Somatic mutation profile of tumor specimen C3L-02102-02 (aliquot CPT0168930006) from CPTAC case C3L-02102, project CPTAC-3 (Skin — Nevi and Melanomas). Sex at birth: male; Vital status: Alive; Primary diagnosis: Malignant melanoma, NOS; Tissue or organ of origin: Skin, NOS; AJCC pathologic stage: Stage 0; Age at diagnosis: 65.1 years (23,767 days).
Specimen C3L-02102-02: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Metastatic; Specimen type: Solid Tissue; Biospecimen anatomic site: Lymph Node; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 47d944bd-eef5-4e2b-853b-e2b141be0420.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3L-02102-31 (Blood Derived Normal), aliquot CPT0167490002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/57ab9272-3d27-465c-b00f-0f87dc5bc8c2

The open-access MAF lists 1,411 somatic variants for this specimen: 881 protein-altering or splice-affecting, 473 silent, 57 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 822, Silent 473, Nonsense Mutation 45, Intron 43, Splice Region 10, 5'Flank 5, 3'UTR 5, Splice Site 2, 5'UTR 2, Translation Start Site 2, 3'Flank 1, RNA 1.

Variants (750 of 1,411; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- DNAH5 | c.8465G>A p.W2822* | Nonsense Mutation (SNP) | VAF 14/302 reads (5%) | catalogued as rs1060501455; ClinVar: pathogenic; called by muse, mutect2
- GRIN2A | c.2191G>A p.D731N | Missense Mutation (SNP) | VAF 21/324 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs796052549, CM138250, COSV58045061; ClinVar: likely pathogenic; called by muse, mutect2
- KCNH2 | c.1610G>A p.R537Q | Missense Mutation (SNP) | VAF 58/451 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as rs794728373, COSV51205142; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- A2M | c.2495C>T p.P832L | Missense Mutation (SNP) | VAF 22/322 reads (7%) | SIFT tolerated (0.15); PolyPhen benign (0.062); catalogued as rs1415142582; called by muse, mutect2
- AASDHPPT | c.857C>T p.P286L | Missense Mutation (SNP) | VAF 34/490 reads (7%) | SIFT tolerated (0.23); PolyPhen benign (0.025); catalogued as COSV53788434; called by muse, mutect2
- ABCA6 | c.3704C>T p.S1235F | Missense Mutation (SNP) | VAF 20/267 reads (7%) | SIFT deleterious (0.04); PolyPhen benign (0.013); catalogued as rs1322663643, COSV52646517; called by muse, mutect2
- ABCC11 | c.3607G>A p.G1203S | Missense Mutation (SNP) | VAF 45/521 reads (9%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.971); catalogued as rs769368539, COSV62322938; called by muse, mutect2
- ABCG5 | c.141C>T p.V47= | Splice Region (SNP) | VAF 18/384 reads (5%) | catalogued as COSV53211906; called by muse, mutect2
- ACSM2B | c.420G>A p.M140I | Missense Mutation (SNP) | VAF 21/265 reads (8%) | SIFT deleterious (0); PolyPhen benign (0.145); catalogued as COSV61656609; called by muse, mutect2
- ACSS3 | c.1730C>T p.S577F | Missense Mutation (SNP) | VAF 15/323 reads (5%) | SIFT tolerated (0.1); PolyPhen benign (0.03); catalogued as COSV54091558; called by muse, mutect2
- ADAMTS6 | c.1990G>A p.E664K | Missense Mutation (SNP) | VAF 26/452 reads (6%) | SIFT tolerated (0.28); PolyPhen possibly damaging (0.682); catalogued as rs1383210373; called by muse, mutect2
- ADD2 | c.520G>A p.G174R | Missense Mutation (SNP) | VAF 22/392 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52454309; called by muse, mutect2
- ADGRV1 | c.3856G>A p.E1286K | Missense Mutation (SNP) | VAF 27/523 reads (5%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.493); catalogued as rs868240938, COSV67995300; called by muse, mutect2
- ADH1B | c.896C>T p.S299F | Missense Mutation (SNP) | VAF 24/485 reads (5%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.809); catalogued as COSV59299175; called by muse, mutect2
- AGT | c.1222G>A p.E408K | Missense Mutation (SNP) | VAF 28/524 reads (5%) | SIFT tolerated (0.35); PolyPhen benign (0.044); catalogued as rs886046081; ClinVar: uncertain significance; called by muse, mutect2
- ALDH2 | c.479C>T p.T160I | Missense Mutation (SNP) | VAF 25/500 reads (5%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.759); catalogued as COSV55665068; called by muse, mutect2
- AMER1 | c.634C>T p.P212S | Missense Mutation (SNP) | VAF 26/350 reads (7%) | SIFT tolerated (0.22); PolyPhen benign (0.031); catalogued as COSV57656908; called by muse, mutect2
- AMER3 | c.607C>T p.P203S | Missense Mutation (SNP) | VAF 29/608 reads (5%) | SIFT tolerated (0.26); PolyPhen benign (0.039); catalogued as rs866438211, COSV58465545; called by muse, mutect2
- ANK3 | c.10681G>A p.E3561K | Missense Mutation (SNP) | VAF 23/469 reads (5%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.054); catalogued as rs867794288; called by muse, mutect2
- ANKFN1 | c.286G>A p.A96T | Missense Mutation (SNP) | VAF 50/462 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1474685199; called by muse, mutect2
- ANKIB1 | c.2965C>T p.P989S | Missense Mutation (SNP) | VAF 36/303 reads (12%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.996); catalogued as COSV56065143; called by muse, mutect2, varscan2
- ANKRD2 | c.331G>A p.G111R | Missense Mutation (SNP) | VAF 30/615 reads (5%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.989); catalogued as COSV53969905; called by muse, mutect2
- ANO4 | c.1457C>T p.S486F (on ENST00000392977 / NM_001286615.2; = p.S451F on NM_178826.4) | Missense Mutation (SNP) | VAF 28/494 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.949); catalogued as COSV54610208; called by muse, mutect2
- APCS | c.21G>A p.W7* | Nonsense Mutation (SNP) | VAF 25/363 reads (7%) | catalogued as COSV54817641; called by muse, mutect2
- APOB | c.10899G>A p.W3633* | Nonsense Mutation (SNP) | VAF 21/404 reads (5%) | catalogued as COSV51938071; called by muse, mutect2
- APOB | c.1478G>A p.G493E | Missense Mutation (SNP) | VAF 18/307 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.861); catalogued as COSV51922910; called by muse, mutect2
- ARHGAP30 | c.2410G>A p.E804K | Missense Mutation (SNP) | VAF 35/498 reads (7%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0); catalogued as rs1035614070; called by muse, mutect2
- ARHGAP44 | c.1136G>A p.R379Q | Missense Mutation (SNP) | VAF 27/358 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.909); catalogued as rs867501468; called by muse, mutect2
- ART1 | c.518G>A p.R173Q | Missense Mutation (SNP) | VAF 46/609 reads (8%) | SIFT tolerated (0.46); PolyPhen benign (0.02); catalogued as rs762197868, COSV51705173; called by muse, mutect2
- ASIC2 | c.1243G>A p.E415K | Missense Mutation (SNP) | VAF 14/298 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56767597; called by muse, mutect2
- ASPM | c.6955C>T p.Q2319* | Nonsense Mutation (SNP) | VAF 23/396 reads (6%) | catalogued as COSV54134664; called by muse, mutect2
- ASTN2 | c.3692C>T p.S1231L (on ENST00000313400 / NM_001365069.1; = p.S1180L on NM_014010.5) | Missense Mutation (SNP) | VAF 28/532 reads (5%) | SIFT deleterious (0); PolyPhen benign (0.313); catalogued as rs1458214989, COSV55999388; called by muse, mutect2
- ASXL3 | c.4324G>A p.G1442R | Missense Mutation (SNP) | VAF 28/460 reads (6%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.669); catalogued as COSV99324544; called by muse, mutect2
- ATP10D | c.2278G>A p.G760R | Missense Mutation (SNP) | VAF 24/436 reads (6%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.84); catalogued as COSV99904988; called by muse, mutect2
- BEND2 | c.1531C>T p.R511C | Missense Mutation (SNP) | VAF 29/286 reads (10%) | SIFT tolerated (0.22); PolyPhen benign (0.035); catalogued as rs753955004, COSV66215001; called by muse, mutect2
- BIN2 | c.376G>A p.E126K | Missense Mutation (SNP) | VAF 18/296 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV57207000; called by muse, mutect2
- BMPR2 | c.1361C>T p.S454F | Missense Mutation (SNP) | VAF 20/376 reads (5%) | SIFT deleterious (0); PolyPhen possibly damaging (0.902); catalogued as rs1347010932; called by muse, mutect2
- BNC1 | c.2903C>T p.S968L | Missense Mutation (SNP) | VAF 30/483 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs968421847, COSV61756810; called by muse, mutect2
- BNC2 | c.1663C>T p.P555S | Missense Mutation (SNP) | VAF 28/428 reads (7%) | SIFT tolerated (0.35); PolyPhen benign (0); catalogued as COSV66149124; called by muse, mutect2
- BRAT1 | c.773C>T p.S258L | Missense Mutation (SNP) | VAF 24/481 reads (5%) | SIFT tolerated (0.75); PolyPhen benign (0.089); catalogued as rs888197625, COSV61394704; called by muse, mutect2
- BRWD3 | c.1565C>T p.S522L | Missense Mutation (SNP) | VAF 13/210 reads (6%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.992); catalogued as COSV64751984; called by muse, mutect2
- BVES | c.198G>A p.M66I | Missense Mutation (SNP) | VAF 16/370 reads (4%) | SIFT tolerated (0.29); PolyPhen benign (0.092); catalogued as COSV58950301; called by muse, mutect2
- C10orf71 | c.1088G>A p.G363E | Missense Mutation (SNP) | VAF 20/428 reads (5%) | SIFT tolerated (0.39); PolyPhen benign (0.013); catalogued as rs985271678, COSV100109959, COSV60505874; called by muse, mutect2
- C1QTNF9B | c.227G>A p.R76Q | Missense Mutation (SNP) | VAF 30/197 reads (15%) | SIFT tolerated (0.49); PolyPhen benign (0.003); catalogued as rs1463638854, COSV65943913; called by muse, mutect2, varscan2
- C1S | c.1921C>T p.P641S | Missense Mutation (SNP) | VAF 36/488 reads (7%) | SIFT tolerated (0.06); PolyPhen benign (0.062); catalogued as rs782586920, COSV61070589; called by muse, mutect2
- C2orf78 | c.1682G>A p.R561K | Missense Mutation (SNP) | VAF 36/423 reads (9%) | SIFT tolerated (0.21); PolyPhen probably damaging (0.926); catalogued as rs752768790; called by muse, mutect2
- C2orf92 | c.80C>T p.P27L | Missense Mutation (SNP) | VAF 30/424 reads (7%) | SIFT tolerated (1); PolyPhen probably damaging (0.995); catalogued as rs1001084210; called by muse, mutect2
- CA3 | c.188G>A p.G63E | Missense Mutation (SNP) | VAF 26/400 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53409166; called by muse, mutect2
- CACNA1A | c.5503G>A p.D1835N | Missense Mutation (SNP) | VAF 28/538 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100801834; called by muse, mutect2
- CACNA1G | c.3673G>A p.D1225N | Missense Mutation (SNP) | VAF 25/385 reads (6%) | SIFT deleterious (0.05); PolyPhen benign (0.003); catalogued as rs1171766628; called by muse, mutect2
- CALB1 | c.634G>A p.D212N | Missense Mutation (SNP) | VAF 21/413 reads (5%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.997); catalogued as COSV55366772; called by muse, mutect2
- CAMKK1 | c.1418C>T p.S473F | Missense Mutation (SNP) | VAF 35/430 reads (8%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.806); catalogued as COSV50114929; called by muse, mutect2
- CARD11 | c.332C>T p.P111L | Missense Mutation (SNP) | VAF 16/352 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV62716895; called by muse, mutect2
- CATSPER1 | c.298C>T p.P100S | Missense Mutation (SNP) | VAF 38/630 reads (6%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.749); catalogued as rs1244121807, COSV56410397; called by muse, mutect2
- CATSPERB | c.2786C>T p.S929L | Missense Mutation (SNP) | VAF 30/444 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.903); catalogued as COSV56429745; called by muse, mutect2
- CCDC153 | c.64G>A p.G22S | Missense Mutation (SNP) | VAF 31/440 reads (7%) | SIFT tolerated (0.27); PolyPhen benign (0.03); catalogued as rs1261064711; called by muse, mutect2
- CCDC27 | c.377G>A p.R126K | Missense Mutation (SNP) | VAF 43/464 reads (9%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as COSV53904236; called by muse, mutect2
- CCDC63 | c.763C>T p.L255F | Missense Mutation (SNP) | VAF 27/479 reads (6%) | SIFT deleterious (0.03); PolyPhen benign (0.178); catalogued as COSV57528650; called by muse, mutect2
- CCDC68 | c.276G>A p.M92I | Missense Mutation (SNP) | VAF 22/311 reads (7%) | SIFT tolerated (0.1); PolyPhen benign (0.012); catalogued as COSV61603858, COSV61604145; called by muse, mutect2
- CCR4 | c.934C>T p.R312C | Missense Mutation (SNP) | VAF 22/336 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.926); catalogued as rs1432823572, COSV58381780; called by muse, mutect2
- CD163L1 | c.3950G>A p.G1317E | Missense Mutation (SNP) | VAF 23/453 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs867081460, COSV58011299; called by muse, mutect2
- CD163L1 | c.1928G>A p.G643E | Missense Mutation (SNP) | VAF 31/500 reads (6%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.779); catalogued as COSV58011409; called by muse, mutect2
- CD22 | c.2380G>A p.V794I | Missense Mutation (SNP) | VAF 22/333 reads (7%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.991); catalogued as COSV50053122; called by muse, mutect2
- CD93 | c.469C>T p.L157F | Missense Mutation (SNP) | VAF 49/598 reads (8%) | SIFT deleterious (0.04); PolyPhen benign (0.066); catalogued as rs758462469; called by muse, mutect2
- CDH10 | c.2219G>A p.G740E | Missense Mutation (SNP) | VAF 21/408 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52570603, COSV52576617; called by muse, mutect2
- CDH10 | c.1392C>T p.I464= | Splice Region (SNP) | VAF 19/220 reads (9%) | catalogued as rs1398866687; called by muse, mutect2
- CDH8 | c.1663C>T p.L555F | Missense Mutation (SNP) | VAF 24/264 reads (9%) | SIFT deleterious (0.01); PolyPhen benign (0.012); catalogued as rs1394168835; called by muse, mutect2
- CDH9 | c.1927G>A p.E643K | Missense Mutation (SNP) | VAF 32/358 reads (9%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.981); catalogued as COSV50370647, COSV50459979; called by muse, mutect2
- CEP170 | c.4442A>C p.K1481T | Missense Mutation (SNP) | VAF 23/368 reads (6%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as COSV60505918; called by muse, mutect2
- CES3 | c.643C>T p.P215S | Missense Mutation (SNP) | VAF 41/565 reads (7%) | SIFT tolerated (0.22); PolyPhen benign (0.012); catalogued as rs749152138; called by muse, mutect2
- CHAD | c.94G>A p.D32N | Missense Mutation (SNP) | VAF 27/477 reads (6%) | SIFT deleterious (0.04); PolyPhen benign (0.262); catalogued as COSV51973140; called by muse, mutect2
- CHRNB1 | c.634C>T p.H212Y | Missense Mutation (SNP) | VAF 21/378 reads (6%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.966); catalogued as rs1330559735; called by muse, mutect2
- CLDN1 | c.544C>T p.L182F | Missense Mutation (SNP) | VAF 20/447 reads (4%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.998); catalogued as rs1289483522; called by muse, mutect2
- CLGN | c.1672G>A p.E558K | Missense Mutation (SNP) | VAF 13/210 reads (6%) | SIFT tolerated (0.15); PolyPhen benign (0.007); catalogued as COSV57774015; called by muse, mutect2
- CNTN5 | c.1136C>T p.S379F | Missense Mutation (SNP) | VAF 23/380 reads (6%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.702); catalogued as rs866845091, COSV54279011; called by muse, mutect2
- CNTNAP2 | c.3889G>A p.E1297K | Missense Mutation (SNP) | VAF 85/689 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.73); catalogued as rs777946931, COSV62162609; called by muse, mutect2, varscan2
- CNTNAP3 | c.2477C>T p.S826F | Missense Mutation (SNP) | VAF 18/424 reads (4%) | SIFT tolerated (0.53); PolyPhen benign (0.125); catalogued as COSV52664256; called by muse, mutect2
- COL21A1 | c.2095G>A p.D699N | Missense Mutation (SNP) | VAF 26/314 reads (8%) | SIFT tolerated (0.19); PolyPhen probably damaging (0.976); catalogued as rs1428750512; called by muse, mutect2
- COL2A1 | c.3583G>A p.E1195K | Missense Mutation (SNP) | VAF 17/373 reads (5%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.989); catalogued as rs1186663188, COSV61527447; called by muse, mutect2
- COL3A1 | c.1540C>T p.P514S | Missense Mutation (SNP) | VAF 24/375 reads (6%) | SIFT tolerated (0.28); PolyPhen possibly damaging (0.589); catalogued as rs1234299141; called by muse, mutect2
- COL4A1 | c.3490G>A p.E1164K | Missense Mutation (SNP) | VAF 24/404 reads (6%) | SIFT tolerated (0.25); PolyPhen probably damaging (0.992); catalogued as COSV101011544; called by muse, mutect2
- COL4A3 | c.79G>A p.A27T | Missense Mutation (SNP) | VAF 38/392 reads (10%) | SIFT tolerated (0.65); PolyPhen benign (0); catalogued as rs1327569810; called by muse, mutect2
- COL4A5 | c.4045G>A p.E1349K | Missense Mutation (SNP) | VAF 24/272 reads (9%) | SIFT tolerated (0.05); PolyPhen benign (0.007); catalogued as CD115550, COSV60364536; called by muse, mutect2
- COL5A2 | c.4229G>A p.G1410E | Missense Mutation (SNP) | VAF 22/418 reads (5%) | SIFT deleterious (0); PolyPhen possibly damaging (0.69); catalogued as COSV66411373; called by muse, mutect2
- COL5A2 | c.2827C>T p.L943F | Missense Mutation (SNP) | VAF 28/570 reads (5%) | SIFT tolerated (0.71); PolyPhen possibly damaging (0.738); catalogued as COSV66412953; called by muse, mutect2
- COL6A5 | c.548C>T p.S183F | Missense Mutation (SNP) | VAF 16/286 reads (6%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.878); catalogued as COSV55213057; called by muse, mutect2
- COLEC12 | c.1688G>A p.G563E | Missense Mutation (SNP) | VAF 38/585 reads (6%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs1285161607; called by muse, mutect2
- CPM | c.250G>A p.G84R | Missense Mutation (SNP) | VAF 25/301 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV58032644; called by muse, mutect2
- CPXCR1 | c.822G>A p.W274* | Nonsense Mutation (SNP) | VAF 23/185 reads (12%) | catalogued as COSV104370547, COSV52163917; called by muse, mutect2, varscan2
- CPXM1 | c.143C>T p.P48L | Missense Mutation (SNP) | VAF 28/437 reads (6%) | SIFT tolerated, low confidence (0.6); PolyPhen benign (0); catalogued as rs1287093503; called by muse, mutect2
- CRB1 | c.3497C>T p.P1166L | Missense Mutation (SNP) | VAF 26/352 reads (7%) | SIFT tolerated (0.24); PolyPhen benign (0.033); catalogued as COSV66333601; called by muse, mutect2
- CRB2 | c.3305C>T p.P1102L | Missense Mutation (SNP) | VAF 35/584 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1033673141; called by muse, mutect2
- CRNKL1 | c.370C>T p.P124S | Missense Mutation (SNP) | VAF 34/512 reads (7%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.115); catalogued as rs1410583835, COSV55620275; called by muse, mutect2
- CSMD2 | c.2471G>A p.G824E | Missense Mutation (SNP) | VAF 24/476 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1261489927; called by muse, mutect2
- CST8 | c.110C>T p.P37L | Missense Mutation (SNP) | VAF 29/334 reads (9%) | SIFT tolerated (0.26); PolyPhen benign (0.003); catalogued as rs1399379143; called by muse, mutect2
- CT47B1 | c.584C>T p.S195L | Missense Mutation (SNP) | VAF 28/283 reads (10%) | SIFT tolerated (0.36); PolyPhen possibly damaging (0.776); catalogued as rs1474586929, COSV64891018, COSV64891201; called by muse, mutect2, varscan2
- CTF1 | c.62C>T p.P21L | Missense Mutation (SNP) | VAF 18/404 reads (4%) | SIFT deleterious (0.01); PolyPhen benign (0.217); catalogued as COSV53064705; called by muse, mutect2
- CTNND2 | c.2482C>T p.L828F | Missense Mutation (SNP) | VAF 15/345 reads (4%) | SIFT tolerated (0.56); PolyPhen benign (0.003); catalogued as COSV58935211; called by muse, mutect2
- CUX2 | c.2605C>T p.P869S | Missense Mutation (SNP) | VAF 35/641 reads (5%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.946); catalogued as COSV55646583; called by muse, mutect2
- CUX2 | c.2606C>T p.P869L | Missense Mutation (SNP) | VAF 36/641 reads (6%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.965); catalogued as rs1238553608; called by muse, mutect2
- CX3CR1 | c.659C>T p.S220F | Missense Mutation (SNP) | VAF 22/418 reads (5%) | SIFT tolerated (0.73); PolyPhen benign (0.037); catalogued as rs928981544, COSV64193082; called by muse, mutect2
- CYP2C19 | c.658C>T p.P220S | Missense Mutation (SNP) | VAF 13/180 reads (7%) | SIFT tolerated (0.19); PolyPhen benign (0.11); catalogued as rs867067400, COSV64907708; called by muse, mutect2
- CYP4A22 | c.1172G>A p.R391K | Missense Mutation (SNP) | VAF 40/656 reads (6%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.79); catalogued as COSV53741746; called by muse, mutect2
- CYSLTR1 | c.382C>T p.P128S | Missense Mutation (SNP) | VAF 24/276 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100964704; called by muse, mutect2
- DBNL | c.964C>T p.P322S (on ENST00000448521 / NM_001014436.3; = p.P323S on NM_014063.7) | Missense Mutation (SNP) | VAF 30/417 reads (7%) | SIFT tolerated (0.22); PolyPhen benign (0.014); catalogued as rs1257912005; called by muse, mutect2
- DCAF1 | c.2047C>T p.Q683* | Nonsense Mutation (SNP) | VAF 26/421 reads (6%) | catalogued as COSV60040669; called by muse, mutect2
- DCAF8L1 | c.353G>A p.R118Q | Missense Mutation (SNP) | VAF 27/278 reads (10%) | SIFT tolerated, low confidence (0.71); PolyPhen benign (0.003); catalogued as rs755353352; called by muse, mutect2, varscan2
- DDX46 | c.1714C>T p.R572C | Missense Mutation (SNP) | VAF 23/427 reads (5%) | SIFT deleterious (0); PolyPhen possibly damaging (0.658); catalogued as COSV62799236; called by muse, mutect2
- DENND2B | c.1162C>T p.P388S | Missense Mutation (SNP) | VAF 30/459 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1193345546, COSV58202129; called by muse, mutect2
- DIO2 | c.728G>A p.G243E | Missense Mutation (SNP) | VAF 21/441 reads (5%) | SIFT deleterious (0.01); PolyPhen benign (0.307); catalogued as COSV101375816, COSV70445331; called by muse, mutect2
- DMGDH | c.937G>A p.E313K | Missense Mutation (SNP) | VAF 24/368 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV99669396; called by muse, mutect2
- DNAH3 | c.8707C>T p.P2903S | Missense Mutation (SNP) | VAF 24/520 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1248276741; called by muse, mutect2
- DNAH6 | c.10778G>A p.G3593E | Missense Mutation (SNP) | VAF 38/524 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs866325994; called by muse, mutect2
- DNAH8 | c.8435C>T p.S2812L | Missense Mutation (SNP) | VAF 20/360 reads (6%) | SIFT deleterious (0); PolyPhen benign (0.166); catalogued as rs1048366327, COSV59433913; called by muse, mutect2
- DNAJB8 | c.521C>T p.S174F | Missense Mutation (SNP) | VAF 36/512 reads (7%) | SIFT tolerated (0.13); PolyPhen benign (0.191); catalogued as rs865944606; called by muse, mutect2
- DSC3 | c.577G>A p.G193R | Missense Mutation (SNP) | VAF 31/361 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV64574524; called by muse, mutect2
- DSG1 | c.3053C>T p.S1018F | Missense Mutation (SNP) | VAF 19/418 reads (5%) | SIFT deleterious (0); PolyPhen possibly damaging (0.823); catalogued as COSV57137053; called by muse, mutect2
- EDNRA | c.1085C>T p.S362L | Missense Mutation (SNP) | VAF 18/358 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV100163496; called by muse, mutect2
- EGF | c.244C>T p.H82Y | Missense Mutation (SNP) | VAF 20/519 reads (4%) | SIFT deleterious (0.05); PolyPhen benign (0.349); catalogued as rs902596253; called by muse, mutect2
- EIF4G3 | c.1672C>T p.P558S | Missense Mutation (SNP) | VAF 25/430 reads (6%) | SIFT tolerated, low confidence (0.28); PolyPhen benign (0); catalogued as rs1439906536; called by muse, mutect2
- ENAM | c.1939G>A p.E647K | Missense Mutation (SNP) | VAF 20/376 reads (5%) | SIFT tolerated (0.11); PolyPhen benign (0.263); catalogued as COSV68536004; called by muse, mutect2
- ENPEP | c.2725G>A p.E909K | Missense Mutation (SNP) | VAF 14/234 reads (6%) | SIFT tolerated (0.06); PolyPhen benign (0.106); catalogued as COSV54449878, COSV99486993; called by muse, mutect2
- ENPP5 | c.1169G>A p.G390E | Missense Mutation (SNP) | VAF 31/498 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1223906343; called by muse, mutect2
- ERCC4 | c.1543C>T p.R515C | Missense Mutation (SNP) | VAF 25/470 reads (5%) | SIFT tolerated (0.09); PolyPhen benign (0); catalogued as rs866657450, COSV61313631; called by muse, mutect2
- EXPH5 | c.2702C>T p.P901L | Missense Mutation (SNP) | VAF 16/406 reads (4%) | SIFT tolerated (0.06); PolyPhen benign (0.222); catalogued as COSV56198991; called by muse, mutect2
- EYA4 | c.1757G>A p.G586E (on ENST00000531901 / NM_001301013.1; = p.G580E on NM_004100.5) | Missense Mutation (SNP) | VAF 22/394 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs866696222, COSV62061225; called by muse, mutect2
- F13A1 | c.1128G>A p.W376* | Nonsense Mutation (SNP) | VAF 19/314 reads (6%) | catalogued as CM060260, COSV53555912; called by muse, mutect2
- F13A1 | c.515G>A p.R172Q | Missense Mutation (SNP) | VAF 50/533 reads (9%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.877); catalogued as rs376147795, CM146351; called by muse, mutect2
- F8 | c.6734C>T p.P2245L | Missense Mutation (SNP) | VAF 14/188 reads (7%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.953); catalogued as COSV100371808; called by muse, mutect2
- FAM135B | c.3137C>T p.S1046F | Missense Mutation (SNP) | VAF 33/489 reads (7%) | SIFT deleterious (0.01); PolyPhen benign (0.03); catalogued as COSV52704222, COSV99422994; called by muse, mutect2
- FAM135B | c.2170C>T p.H724Y | Missense Mutation (SNP) | VAF 27/474 reads (6%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.946); catalogued as COSV99423418; called by muse, mutect2
- FAM160A2 | c.2141C>T p.P714L (on ENST00000449352 / NM_001098794.2; = p.P728L on NM_032127.4) | Missense Mutation (SNP) | VAF 32/592 reads (5%) | SIFT tolerated (0.15); PolyPhen benign (0); catalogued as rs1180589926, COSV56410373; called by muse, mutect2
- FAM47C | c.2974G>A p.E992K | Missense Mutation (SNP) | VAF 24/261 reads (9%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.543); catalogued as rs1556333449; called by muse, mutect2
- FASN | c.5138C>T p.P1713L | Missense Mutation (SNP) | VAF 66/508 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs112806006; called by muse, mutect2, varscan2
- FAT3 | c.7577G>A p.G2526E | Missense Mutation (SNP) | VAF 18/339 reads (5%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as rs1415027188, COSV53114196; called by muse, mutect2
- FBN3 | c.8111C>T p.S2704F | Missense Mutation (SNP) | VAF 24/380 reads (6%) | SIFT tolerated (0.1); PolyPhen benign (0.118); catalogued as rs1459927099; called by muse, mutect2
- FER1L5 | c.3868C>T p.Q1290* (on ENST00000623019; = p.Q1263* on NM_001293083.2) | Nonsense Mutation (SNP) | VAF 30/545 reads (6%) | catalogued as rs1173002033; called by muse, mutect2
- FERD3L | c.247G>A p.G83R | Missense Mutation (SNP) | VAF 37/642 reads (6%) | SIFT tolerated (0.4); PolyPhen benign (0); catalogued as rs1417304737, COSV51762711; called by muse, mutect2
- FGFR2 | c.979C>T p.L327F | Missense Mutation (SNP) | VAF 16/473 reads (3%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as CM156022, COSV60663645; called by muse, mutect2
- FHL5 | c.127G>A p.E43K | Missense Mutation (SNP) | VAF 23/254 reads (9%) | SIFT tolerated (0.08); PolyPhen benign (0.021); catalogued as rs1290467874; called by muse, mutect2
- FKBP10 | c.403C>T p.P135S | Missense Mutation (SNP) | VAF 24/324 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1029623005; called by muse, mutect2
- FKRP | c.350C>T p.P117L | Missense Mutation (SNP) | VAF 41/748 reads (5%) | SIFT tolerated (0.07); PolyPhen benign (0.003); catalogued as rs941905630; called by muse, mutect2
- FRMPD4 | c.2161G>A p.D721N | Missense Mutation (SNP) | VAF 29/256 reads (11%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.627); catalogued as rs147167664, COSV66213829; called by muse, mutect2, varscan2
- GABRQ | c.1148G>A p.G383E | Missense Mutation (SNP) | VAF 25/220 reads (11%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as rs868957830; called by muse, mutect2, varscan2
- GAL3ST4 | c.17C>T p.P6L | Missense Mutation (SNP) | VAF 41/364 reads (11%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.005); catalogued as rs1261794430; called by muse, mutect2, varscan2
- GGN | c.1103G>A p.G368E | Missense Mutation (SNP) | VAF 46/630 reads (7%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.943); catalogued as COSV99287729; called by muse, mutect2
- GIMAP8 | c.526G>A p.D176N | Missense Mutation (SNP) | VAF 22/470 reads (5%) | SIFT deleterious (0.04); PolyPhen benign (0.233); catalogued as rs866765845, COSV56234905; called by muse, mutect2
- GJA8 | c.199G>A p.D67N | Missense Mutation (SNP) | VAF 35/547 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs782805555, COSV53789424; called by muse, mutect2
- GLYATL3 | c.724G>A p.G242R | Missense Mutation (SNP) | VAF 32/578 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1255658713; called by muse, mutect2
- GPR50 | c.1078G>A p.E360K | Missense Mutation (SNP) | VAF 34/329 reads (10%) | SIFT tolerated (0.12); PolyPhen benign (0.102); catalogued as COSV54437487; called by muse, mutect2, varscan2
- GRIN2B | c.2635G>A p.E879K | Missense Mutation (SNP) | VAF 16/344 reads (5%) | SIFT tolerated (0.08); PolyPhen benign (0.347); catalogued as COSV74205047; called by muse, mutect2
- GRXCR2 | c.418G>A p.D140N | Missense Mutation (SNP) | VAF 25/456 reads (5%) | SIFT deleterious (0.01); PolyPhen benign (0.033); catalogued as rs1268751064, COSV65062068; called by muse, mutect2
- GUCY1A2 | c.2135C>T p.S712L | Missense Mutation (SNP) | VAF 25/412 reads (6%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.574); catalogued as rs1383258563, COSV56477773; called by muse, mutect2
- GUCY2C | c.3205G>A p.E1069K | Missense Mutation (SNP) | VAF 14/332 reads (4%) | SIFT tolerated, low confidence (0.82); PolyPhen benign (0.035); catalogued as COSV53788424; called by muse, mutect2
- GXYLT2 | c.1232G>A p.G411E | Missense Mutation (SNP) | VAF 26/557 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as rs1340742441, COSV67474600; called by muse, mutect2
- H4C7 | c.190G>A p.E64K | Missense Mutation (SNP) | VAF 31/563 reads (6%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.597); catalogued as COSV55099518; called by muse, mutect2
- HCN1 | c.709C>T p.L237F | Missense Mutation (SNP) | VAF 18/380 reads (5%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.463); catalogued as COSV100299111; called by muse, mutect2
- HELZ | c.4066C>T p.P1356S | Missense Mutation (SNP) | VAF 49/586 reads (8%) | SIFT tolerated, low confidence (0.31); PolyPhen benign (0.3); catalogued as rs749763290, COSV100698702; called by muse, mutect2
- HEMGN | c.520C>T p.P174S | Missense Mutation (SNP) | VAF 24/429 reads (6%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.451); catalogued as COSV52328260; called by muse, mutect2
- HNRNPCL1 | c.788G>A p.G263E | Missense Mutation (SNP) | VAF 29/642 reads (5%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.999); catalogued as COSV58610662; called by muse, mutect2
- HRH3 | c.929C>T p.S310F | Missense Mutation (SNP) | VAF 37/548 reads (7%) | SIFT tolerated (0.08); PolyPhen benign (0.014); catalogued as rs1339125011; called by muse, mutect2
- HS3ST1 | c.377C>T p.S126L | Missense Mutation (SNP) | VAF 45/515 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as rs975454953; called by muse, mutect2
- HSPA8 | c.1876C>T p.P626S | Missense Mutation (SNP) | VAF 32/474 reads (7%) | SIFT tolerated, low confidence (0.26); PolyPhen possibly damaging (0.901); catalogued as COSV57085822; called by muse, mutect2
- HTR2C | c.562C>T p.P188S | Missense Mutation (SNP) | VAF 16/157 reads (10%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.889); catalogued as rs868956836, COSV52204464; called by muse, mutect2, varscan2
- HTR4 | c.1108G>A p.E370K | Missense Mutation (SNP) | VAF 17/382 reads (4%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0); catalogued as COSV100087136; called by muse, mutect2
- IGHV3-23 | c.311G>A p.S104N | Missense Mutation (SNP) | VAF 15/229 reads (7%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0.194); catalogued as rs531804121; called by muse, mutect2
- IGSF1 | c.2752C>T p.R918W | Missense Mutation (SNP) | VAF 27/246 reads (11%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.536); catalogued as rs201712796, COSV63836956; called by muse, mutect2, varscan2
- IL12RB2 | c.278C>T p.P93L | Missense Mutation (SNP) | VAF 18/490 reads (4%) | SIFT deleterious (0.01); PolyPhen benign (0.355); catalogued as COSV52027509; called by muse, mutect2
- IL31RA | c.1553G>A p.R518Q | Missense Mutation (SNP) | VAF 20/344 reads (6%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.963); catalogued as rs1561123720; called by muse, mutect2
- INTS12 | c.233C>T p.P78L | Missense Mutation (SNP) | VAF 38/480 reads (8%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.997); catalogued as rs1412660381, COSV100415866; called by muse, mutect2
- INTS12 | c.232C>T p.P78S | Missense Mutation (SNP) | VAF 38/477 reads (8%) | SIFT tolerated (0.63); PolyPhen probably damaging (0.996); catalogued as rs923034586; called by muse, mutect2
- IQGAP2 | c.2629G>A p.E877K | Missense Mutation (SNP) | VAF 22/388 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.656); catalogued as COSV57178307; called by muse, mutect2
- IQSEC3 | c.328G>A p.D110N | Missense Mutation (SNP) | VAF 52/1030 reads (5%) | SIFT tolerated, low confidence (0.33); PolyPhen benign (0); catalogued as rs1281152936; called by muse, mutect2
- IQSEC3 | c.2302G>A p.E768K (on ENST00000538872 / NM_001170738.2; = p.E465K on NM_015232.1) | Missense Mutation (SNP) | VAF 20/562 reads (4%) | SIFT tolerated (0.08); PolyPhen benign (0.249); catalogued as rs782575514, COSV58280759, COSV58281502; called by muse, mutect2
- IRF8 | c.649G>A p.G217S | Missense Mutation (SNP) | VAF 26/566 reads (5%) | SIFT tolerated (0.57); PolyPhen benign (0.42); catalogued as COSV51897356; called by muse, mutect2
- ITGBL1 | c.170C>T p.P57L | Missense Mutation (SNP) | VAF 26/542 reads (5%) | SIFT tolerated (0.43); PolyPhen possibly damaging (0.758); catalogued as COSV101098350; called by muse, mutect2
- JAKMIP1 | c.2128G>A p.E710K | Missense Mutation (SNP) | VAF 19/434 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV101290892; called by muse, mutect2
- JUP | c.238G>A p.A80T | Missense Mutation (SNP) | VAF 27/585 reads (5%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs575015278; called by muse, mutect2
- KCNB2 | c.1000G>A p.E334K | Missense Mutation (SNP) | VAF 40/530 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as COSV73051061; called by muse, mutect2
- KCNG2 | c.572C>T p.A191V | Missense Mutation (SNP) | VAF 26/479 reads (5%) | SIFT tolerated (0.28); PolyPhen benign (0.145); catalogued as rs1268189838; called by muse, mutect2
- KCNH6 | c.871G>A p.G291R | Missense Mutation (SNP) | VAF 44/464 reads (9%) | SIFT tolerated (0.83); PolyPhen benign (0.001); catalogued as COSV59001899; called by muse, mutect2
- KCNMA1 | c.1468C>T p.L490F | Missense Mutation (SNP) | VAF 20/362 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54287711; called by muse, mutect2
- KCNQ5 | c.2435G>A p.G812E | Missense Mutation (SNP) | VAF 15/302 reads (5%) | SIFT tolerated, low confidence (1); PolyPhen benign (0.005); catalogued as COSV59683308; called by muse, mutect2
- KCNT2 | c.1067G>A p.R356Q | Missense Mutation (SNP) | VAF 20/410 reads (5%) | SIFT deleterious (0); PolyPhen possibly damaging (0.908); catalogued as COSV54086141; called by muse, mutect2
- KDR | c.1789G>A p.E597K | Missense Mutation (SNP) | VAF 32/490 reads (7%) | SIFT tolerated (0.45); PolyPhen benign (0.079); catalogued as COSV55773192; called by muse, mutect2
- KIAA1210 | c.334G>A p.G112R | Missense Mutation (SNP) | VAF 22/175 reads (13%) | SIFT tolerated, low confidence (0.86); PolyPhen benign (0.142); catalogued as COSV101273953; called by muse, mutect2, varscan2
- KIAA1217 | c.2716C>T p.P906S | Missense Mutation (SNP) | VAF 30/524 reads (6%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.647); catalogued as rs984159630; called by muse, mutect2
- KIAA1328 | c.754C>T p.L252F | Missense Mutation (SNP) | VAF 21/529 reads (4%) | SIFT tolerated (0.26); PolyPhen benign (0.051); catalogued as rs1174454627; called by muse, mutect2
- KIAA1549L | c.4046C>T p.A1349V (on ENST00000321505; = p.A1646V on NM_012194.3) | Missense Mutation (SNP) | VAF 36/468 reads (8%) | SIFT tolerated (0.14); PolyPhen benign (0.087); catalogued as COSV58582678; called by muse, mutect2
- KIF21B | c.3236C>T p.A1079V | Missense Mutation (SNP) | VAF 22/561 reads (4%) | SIFT tolerated (0.36); PolyPhen benign (0.411); catalogued as rs1422573344; called by muse, mutect2
- KIF21B | c.1879G>A p.E627K | Missense Mutation (SNP) | VAF 16/320 reads (5%) | SIFT tolerated (0.13); PolyPhen benign (0.012); catalogued as COSV59763389; called by muse, mutect2
- KIRREL3 | c.223G>A p.D75N | Missense Mutation (SNP) | VAF 46/592 reads (8%) | SIFT tolerated (0.75); PolyPhen benign (0.001); catalogued as rs375403945; called by muse, mutect2
- KLHL30 | c.1412G>A p.G471E | Missense Mutation (SNP) | VAF 26/506 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs904204914; called by muse, mutect2
- KLHL6 | c.1820C>T p.S607L | Missense Mutation (SNP) | VAF 22/478 reads (5%) | SIFT deleterious (0); PolyPhen possibly damaging (0.886); catalogued as COSV58068521; called by muse, mutect2
- KMT2C | c.8335C>T p.L2779F | Missense Mutation (SNP) | VAF 24/309 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV51507030; called by muse, mutect2
- KRT12 | c.161G>A p.G54E | Missense Mutation (SNP) | VAF 28/674 reads (4%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.518); catalogued as rs774610996; called by muse, mutect2
- KRT23 | c.352G>A p.D118N | Missense Mutation (SNP) | VAF 26/454 reads (6%) | SIFT deleterious (0.03); PolyPhen benign (0.214); catalogued as rs765867862, COSV52927350, COSV52929034; called by muse, mutect2
- KRT76 | c.461G>A p.G154E | Missense Mutation (SNP) | VAF 34/497 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); catalogued as COSV100195783, COSV60119197, COSV60121669; called by muse, mutect2
- KRTAP10-5 | c.452C>T p.S151L | Missense Mutation (SNP) | VAF 32/552 reads (6%) | SIFT tolerated (0.1); PolyPhen benign (0.01); catalogued as COSV100555282; called by muse, mutect2
- LCT | c.1058C>T p.S353F | Missense Mutation (SNP) | VAF 30/473 reads (6%) | SIFT tolerated (0.7); PolyPhen benign (0.125); catalogued as rs1464179881; called by muse, mutect2
- LGALS9C | c.239G>A p.G80E | Missense Mutation (SNP) | VAF 25/328 reads (8%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.802); catalogued as COSV60195460; called by muse, mutect2
- LMOD3 | c.757C>T p.P253S | Missense Mutation (SNP) | VAF 22/436 reads (5%) | SIFT tolerated (0.07); PolyPhen benign (0.339); catalogued as COSV70456330; called by muse, mutect2
- LONRF1 | c.2141C>T p.P714L | Missense Mutation (SNP) | VAF 19/362 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1297037939; called by muse, mutect2
- LRFN2 | c.2222G>A p.G741D | Missense Mutation (SNP) | VAF 33/633 reads (5%) | SIFT tolerated (0.63); PolyPhen benign (0.145); catalogued as rs1446280580, COSV57824681; called by muse, mutect2
- LRP2 | c.12193C>T p.R4065* | Nonsense Mutation (SNP) | VAF 16/354 reads (5%) | catalogued as rs1228784624, COSV55545838; called by muse, mutect2
- MAGEB6 | c.271G>A p.E91K | Missense Mutation (SNP) | VAF 33/269 reads (12%) | SIFT tolerated (0.09); PolyPhen benign (0.01); catalogued as COSV100983675; called by muse, mutect2, varscan2
- MAN1A1 | c.1116G>A p.K372= | Splice Region (SNP) | VAF 16/218 reads (7%) | catalogued as COSV63784348; called by muse, mutect2
- MAP3K15 | c.2497G>A p.D833N | Missense Mutation (SNP) | VAF 35/228 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs1230409748, COSV58829431; called by muse, mutect2, varscan2
- MARCHF4 | c.553G>A p.V185I | Missense Mutation (SNP) | VAF 19/436 reads (4%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.615); catalogued as rs1352295822; called by muse, mutect2
- MARCO | c.892G>A p.G298R | Missense Mutation (SNP) | VAF 26/393 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV59054036; called by muse, mutect2
- MARCO | c.1534G>A p.E512K | Missense Mutation (SNP) | VAF 24/392 reads (6%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.945); catalogued as rs866449145, COSV100503356; called by muse, mutect2
- MAS1 | c.37G>A p.E13K | Missense Mutation (SNP) | VAF 17/349 reads (5%) | SIFT tolerated (0.72); PolyPhen benign (0); catalogued as COSV99396790; called by muse, mutect2
- MAST4 | c.113C>T p.S38L | Missense Mutation (SNP) | VAF 26/508 reads (5%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.001); catalogued as COSV68234566; called by muse, mutect2
- MBD5 | c.2701C>T p.P901S | Missense Mutation (SNP) | VAF 31/468 reads (7%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.996); catalogued as COSV68695767; called by muse, mutect2
- MCF2 | c.1594G>A p.D532N | Missense Mutation (SNP) | VAF 11/144 reads (8%) | SIFT tolerated (0.14); PolyPhen benign (0.014); catalogued as rs1405735051; called by muse, mutect2
- MDC1 | c.4619C>T p.S1540F | Missense Mutation (SNP) | VAF 128/891 reads (14%) | SIFT deleterious (0.04); PolyPhen benign (0.309); catalogued as rs1461202402, COSV64525618; called by muse, mutect2, varscan2
- MEFV | c.716G>A p.R239Q | Missense Mutation (SNP) | VAF 33/537 reads (6%) | SIFT tolerated (0.06); PolyPhen benign (0.297); catalogued as COSV54824535; called by muse, mutect2
- MEGF11 | c.544G>A p.G182S | Missense Mutation (SNP) | VAF 44/570 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1400246918; called by muse, mutect2
- MGAT3 | c.964C>A p.P322T | Missense Mutation (SNP) | VAF 28/616 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57867562; called by muse, mutect2
- MGAT3 | c.965C>T p.P322L | Missense Mutation (SNP) | VAF 29/619 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57864920; called by muse, mutect2
- MMP13 | c.332T>C p.L111P | Missense Mutation (SNP) | VAF 16/284 reads (6%) | SIFT tolerated (0.71); PolyPhen benign (0.01); catalogued as COSV52825533; called by muse, mutect2
- MOV10L1 | c.1455G>A p.R485= | Splice Region (SNP) | VAF 16/249 reads (6%) | catalogued as COSV53173260; called by muse, mutect2
- MS4A13 | c.355G>A p.E119K | Missense Mutation (SNP) | VAF 17/323 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as COSV65445580; called by muse, mutect2
- MTUS2 | c.2270C>T p.P757L | Missense Mutation (SNP) | VAF 17/434 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1303568212; called by muse, mutect2
- MUC12 | c.2270C>T p.S757L (on ENST00000379442; = p.S614L on NM_001164462.1) | Missense Mutation (SNP) | VAF 67/1200 reads (6%) | SIFT deleterious (0); PolyPhen benign (0.316); catalogued as rs530749103; called by muse, mutect2
- MUC16 | c.36167G>A p.G12056E | Missense Mutation (SNP) | VAF 17/314 reads (5%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.019); catalogued as rs1268095405; called by muse, mutect2
- MUC16 | c.12881C>T p.S4294F | Missense Mutation (SNP) | VAF 22/414 reads (5%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0.223); catalogued as COSV67455835; called by muse, mutect2
- MUC17 | c.9451G>A p.G3151S | Missense Mutation (SNP) | VAF 55/528 reads (10%) | SIFT tolerated (0.19); PolyPhen benign (0.112); catalogued as COSV60306889; called by muse, mutect2
- MYH11 | c.4444G>A p.E1482K | Missense Mutation (SNP) | VAF 35/720 reads (5%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.973); catalogued as COSV55546598; called by muse, mutect2
- MYH2 | c.1400G>A p.G467D | Missense Mutation (SNP) | VAF 18/402 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99819898; called by muse, mutect2
- MYH4 | c.4066G>A p.E1356K | Missense Mutation (SNP) | VAF 22/600 reads (4%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.936); catalogued as COSV55123365; called by muse, mutect2
- MYH8 | c.2831G>A p.R944K | Missense Mutation (SNP) | VAF 24/514 reads (5%) | SIFT deleterious (0.05); PolyPhen benign (0.085); catalogued as COSV67963962; called by muse, mutect2
- MYO15A | c.1534G>A p.E512K | Missense Mutation (SNP) | VAF 30/480 reads (6%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.234); catalogued as COSV99232262; called by muse, mutect2
- MYO18B | c.6896G>A p.G2299E | Missense Mutation (SNP) | VAF 30/532 reads (6%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.466); catalogued as COSV59132022; called by muse, mutect2
- NARS2 | c.1406C>T p.P469L | Missense Mutation (SNP) | VAF 21/304 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as COSV99807762; called by muse, mutect2
- NBEA | c.8230C>T p.R2744* | Nonsense Mutation (SNP) | VAF 20/467 reads (4%) | catalogued as COSV59765329, COSV59825561; called by muse, mutect2
- NDN | c.886G>A p.E296K | Missense Mutation (SNP) | VAF 26/412 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.956); catalogued as COSV100086200; called by muse, mutect2
- NEBL | c.842C>T p.S281L | Missense Mutation (SNP) | VAF 25/382 reads (7%) | SIFT deleterious (0.01); PolyPhen benign (0.143); catalogued as COSV65805539; called by muse, mutect2
- NEXMIF | c.3842G>A p.G1281E | Missense Mutation (SNP) | VAF 43/319 reads (13%) | SIFT tolerated (0.07); PolyPhen benign (0.117); catalogued as rs1213970754, COSV50026572; called by muse, mutect2, varscan2
- NEXMIF | c.2329C>T p.H777Y | Missense Mutation (SNP) | VAF 20/262 reads (8%) | SIFT tolerated (0.12); PolyPhen benign (0.346); catalogued as COSV50145813; called by muse, mutect2
- NFATC4 | c.2350C>T p.P784S | Missense Mutation (SNP) | VAF 39/599 reads (7%) | SIFT tolerated (0.2); PolyPhen benign (0.158); catalogued as COSV51600456; called by muse, mutect2
- NIBAN1 | c.671A>T p.K224M | Missense Mutation (SNP) | VAF 26/474 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV62284006; called by muse, mutect2
- NKAPL | c.515C>T p.S172L | Missense Mutation (SNP) | VAF 28/478 reads (6%) | SIFT tolerated (0.14); PolyPhen benign (0.003); catalogued as COSV59197300; called by muse, mutect2
- NLRP13 | c.91G>A p.E31K | Missense Mutation (SNP) | VAF 36/511 reads (7%) | SIFT tolerated (0.55); PolyPhen possibly damaging (0.901); catalogued as COSV100738361; called by muse, mutect2
- NLRP5 | c.2522C>T p.S841F | Missense Mutation (SNP) | VAF 32/500 reads (6%) | SIFT tolerated (0.49); PolyPhen benign (0); catalogued as rs1220164982, COSV101173564; called by muse, mutect2
- NOS1 | c.322G>A p.E108K | Missense Mutation (SNP) | VAF 23/490 reads (5%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.993); catalogued as COSV57606745; called by muse, mutect2
- NPFFR2 | c.1222G>A p.E408K | Missense Mutation (SNP) | VAF 18/429 reads (4%) | SIFT tolerated (0.06); PolyPhen benign (0.036); catalogued as COSV58154124; called by muse, mutect2
- NPSR1 | c.62C>T p.S21F | Missense Mutation (SNP) | VAF 45/377 reads (12%) | SIFT tolerated (0.72); PolyPhen benign (0.023); catalogued as COSV62206397; called by muse, mutect2, varscan2
- NRK | c.3130G>A p.E1044K | Missense Mutation (SNP) | VAF 30/312 reads (10%) | SIFT tolerated (0.07); PolyPhen benign (0.001); catalogued as COSV54607991; called by muse, mutect2
- NRXN1 | c.553C>T p.R185C | Missense Mutation (SNP) | VAF 18/490 reads (4%) | SIFT tolerated (0.05); PolyPhen benign (0); catalogued as rs906827517, COSV101279430, COSV68018753; called by muse, mutect2
- NUGGC | c.173G>A p.R58K | Missense Mutation (SNP) | VAF 16/298 reads (5%) | SIFT tolerated (0.26); PolyPhen benign (0.1); catalogued as COSV58434032; called by muse, mutect2
- NUP98 | c.4438G>A p.E1480K (on ENST00000359171 / NM_001365126.1; = p.E1463K on NM_016320.5 and 4 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 52/548 reads (9%) | SIFT tolerated (0.27); PolyPhen benign (0.01); catalogued as rs1564809358; called by muse, mutect2
- OPRM1 | c.1105C>T p.R369C | Missense Mutation (SNP) | VAF 23/432 reads (5%) | SIFT deleterious (0.05); PolyPhen benign (0.031); catalogued as rs1010052797, COSV100001511, COSV57674181; called by muse, mutect2
- OR10A2 | c.83G>A p.G28E | Missense Mutation (SNP) | VAF 28/460 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV56300041; called by muse, mutect2
- OR10A5 | c.805C>T p.P269S | Missense Mutation (SNP) | VAF 29/444 reads (7%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.665); catalogued as COSV55054709; called by muse, mutect2
- OR10R2 | c.296C>T p.P99L | Missense Mutation (SNP) | VAF 26/362 reads (7%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs1394083269; called by muse, mutect2
- OR11G2 | c.514A>G p.T172A | Missense Mutation (SNP) | VAF 21/421 reads (5%) | SIFT deleterious (0.03); PolyPhen benign (0.007); catalogued as rs1193418670, COSV62132429, COSV62132811; called by muse, mutect2
- OR12D2 | c.325G>A p.E109K | Missense Mutation (SNP) | VAF 58/555 reads (10%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.45); catalogued as COSV101011103; called by muse, mutect2, varscan2
- OR14J1 | c.385C>T p.H129Y | Missense Mutation (SNP) | VAF 44/545 reads (8%) | SIFT deleterious (0.03); PolyPhen benign (0.333); catalogued as COSV65845739; called by muse, mutect2
- OR1S1 | c.737G>A p.G246E | Missense Mutation (SNP) | VAF 21/454 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV58706727; called by muse, mutect2
- OR2B3 | c.157C>T p.P53S | Missense Mutation (SNP) | VAF 44/674 reads (7%) | SIFT tolerated (0.26); PolyPhen benign (0.003); catalogued as rs776744751; called by muse, mutect2
- OR2T10 | c.538G>A p.E180K | Missense Mutation (SNP) | VAF 34/432 reads (8%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as COSV57898482; called by muse, mutect2
- OR4A15 | c.876G>A p.M292I | Missense Mutation (SNP) | VAF 28/465 reads (6%) | SIFT tolerated, low confidence (0.16); PolyPhen benign (0.015); catalogued as COSV59033505; called by muse, mutect2
- OR4A47 | c.215C>T p.S72F | Missense Mutation (SNP) | VAF 19/424 reads (4%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.94); catalogued as COSV71445053; called by muse, mutect2
- OR4K15 | c.701C>T p.S234F (on ENST00000305051; = p.S210F on NM_001005486.1) | Missense Mutation (SNP) | VAF 18/354 reads (5%) | SIFT deleterious (0.01); PolyPhen benign (0.078); catalogued as COSV59300274; called by muse, mutect2
- OR51G2 | c.20G>A p.G7E | Missense Mutation (SNP) | VAF 17/383 reads (4%) | SIFT tolerated (0.82); PolyPhen benign (0); catalogued as COSV58992241, COSV58992948; called by muse, mutect2
- OR52A5 | c.241C>T p.P81S | Missense Mutation (SNP) | VAF 28/532 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56614160; called by muse, mutect2
- OR56A4 | c.971C>T p.P324L | Missense Mutation (SNP) | VAF 27/565 reads (5%) | SIFT deleterious (0.02); PolyPhen benign (0.106); catalogued as COSV58110508; called by muse, mutect2
- OR5T2 | c.920C>T p.S307L | Missense Mutation (SNP) | VAF 30/563 reads (5%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as rs761907002, COSV57588609; called by muse, mutect2
- OR6C6 | c.773T>C p.I258T | Missense Mutation (SNP) | VAF 22/387 reads (6%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.062); catalogued as rs1470130897; called by muse, mutect2
- OR6Q1 | c.70G>A p.E24K | Missense Mutation (SNP) | VAF 36/456 reads (8%) | SIFT tolerated (0.22); PolyPhen benign (0.011); catalogued as rs1208591323, COSV56934432; called by muse, mutect2
- OTOL1 | c.109G>A p.E37K | Missense Mutation (SNP) | VAF 27/357 reads (8%) | SIFT tolerated (0.28); PolyPhen benign (0.001); catalogued as COSV60005993; called by muse, mutect2
- OTUD7B | c.323C>T p.S108F | Missense Mutation (SNP) | VAF 26/460 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV64917502; called by muse, mutect2
- PAPPA2 | c.4663G>A p.E1555K | Missense Mutation (SNP) | VAF 23/448 reads (5%) | SIFT tolerated (1); PolyPhen benign (0.01); catalogued as COSV100867640, COSV62802503; called by muse, mutect2
- PATL2 | c.169G>A p.E57K | Missense Mutation (SNP) | VAF 25/492 reads (5%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.188); catalogued as rs1244927115; called by muse, mutect2
- PCDH15 | c.4927G>A p.E1643K | Missense Mutation (SNP) | VAF 20/478 reads (4%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.317); catalogued as COSV57375045; called by muse, mutect2
- PCDHA12 | c.1874G>A p.G625E | Missense Mutation (SNP) | VAF 28/476 reads (6%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.958); catalogued as COSV56495050; called by muse, mutect2
- PCDHA9 | c.1915G>A p.E639K | Missense Mutation (SNP) | VAF 29/518 reads (6%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.763); catalogued as COSV65323835; called by muse, mutect2
- PCDHB12 | c.656C>T p.S219F | Missense Mutation (SNP) | VAF 31/491 reads (6%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.914); catalogued as rs1554286686; called by muse, mutect2
- PCDHB3 | c.172G>A p.E58K | Missense Mutation (SNP) | VAF 21/422 reads (5%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.108); catalogued as COSV50585999; called by muse, mutect2
- PCDHB6 | c.1930G>A p.D644N | Missense Mutation (SNP) | VAF 50/790 reads (6%) | SIFT deleterious (0.01); PolyPhen benign (0.084); catalogued as COSV99170054; called by muse, mutect2
- PCED1B | c.511G>A p.E171K | Missense Mutation (SNP) | VAF 30/486 reads (6%) | SIFT tolerated (1); PolyPhen benign (0.006); catalogued as COSV71394934; called by muse, mutect2
- PCLO | c.764G>A p.G255E | Missense Mutation (SNP) | VAF 47/465 reads (10%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.003); catalogued as COSV100434351; called by muse, mutect2, varscan2
- PEX1 | c.1682C>T p.S561F | Missense Mutation (SNP) | VAF 20/292 reads (7%) | SIFT deleterious (0.02); PolyPhen benign (0.101); catalogued as COSV50394805, COSV50395561; called by muse, mutect2
- PF4 | c.143C>T p.S48F | Missense Mutation (SNP) | VAF 24/547 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV56020820, COSV56021260; called by muse, mutect2
- PGF | c.368C>T p.S123F | Missense Mutation (SNP) | VAF 38/466 reads (8%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.788); catalogued as COSV53124428; called by muse, mutect2
- PHF20 | c.157C>T p.R53C | Missense Mutation (SNP) | VAF 18/491 reads (4%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.996); catalogued as rs1307138088, COSV59184654; called by muse, mutect2
- PIAS1 | c.1033C>T p.P345S | Missense Mutation (SNP) | VAF 24/372 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV51032672; called by muse, mutect2
- PILRB | c.112C>T p.P38S | Missense Mutation (SNP) | VAF 53/390 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.957); catalogued as rs1244719306; called by muse, mutect2, varscan2
- PLB1 | c.2813C>T p.S938F | Missense Mutation (SNP) | VAF 18/399 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100577566; called by muse, mutect2
- PLEC | c.12815C>T p.S4272F (on ENST00000322810 / NM_201380.4; = p.S4162F on NM_000445.5) | Missense Mutation (SNP) | VAF 25/489 reads (5%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as COSV59621926, COSV59671437; called by muse, mutect2
- POU3F4 | c.1013C>T p.P338L | Missense Mutation (SNP) | VAF 23/201 reads (11%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.992); catalogued as rs1555984638, COSV64539365; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- PPARD | c.968C>T p.P323L | Missense Mutation (SNP) | VAF 18/476 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100283368; called by muse, mutect2
- PPCS | c.376C>T p.P126S | Missense Mutation (SNP) | VAF 30/557 reads (5%) | SIFT tolerated (0.13); PolyPhen benign (0.1); catalogued as COSV65333504; called by muse, mutect2
- PPP2R5B | c.598G>T p.E200* | Nonsense Mutation (SNP) | VAF 12/242 reads (5%) | catalogued as COSV99376233; called by muse, mutect2
- PRLR | c.7G>A p.E3K | Missense Mutation (SNP) | VAF 15/324 reads (5%) | SIFT tolerated (0.23); PolyPhen benign (0.015); catalogued as COSV51501476; called by muse, mutect2
- PRMT8 | c.1067G>A p.G356E | Missense Mutation (SNP) | VAF 26/355 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54217524; called by muse, mutect2
- PRMT8 | c.1138G>A p.G380R | Missense Mutation (SNP) | VAF 22/442 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV99713685; called by muse, mutect2
- PROM2 | c.1538G>A p.G513D | Missense Mutation (SNP) | VAF 18/319 reads (6%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.826); catalogued as rs1558745244, COSV58301406; called by muse, mutect2
- PRR12 | c.2549C>T p.P850L (on ENST00000615927; = p.P1671L on NM_020719.3) | Missense Mutation (SNP) | VAF 18/389 reads (5%) | SIFT tolerated (0.16); PolyPhen benign (0.005); catalogued as rs1456398578; called by muse, mutect2
- PRUNE2 | c.1912G>A p.A638T | Missense Mutation (SNP) | VAF 12/436 reads (3%) | SIFT tolerated (0.27); PolyPhen benign (0.005); catalogued as COSV65049280; called by muse, mutect2
- PRUNE2 | c.1349G>A p.S450N | Missense Mutation (SNP) | VAF 44/543 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV65042987; called by muse, mutect2
- PSMD8 | c.124C>T p.R42C | Missense Mutation (SNP) | VAF 32/556 reads (6%) | SIFT deleterious, low confidence (0); PolyPhen benign (0); catalogued as rs867351891; called by muse, mutect2
- PTPRB | c.3598G>A p.D1200N | Missense Mutation (SNP) | VAF 28/446 reads (6%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.95); catalogued as COSV54247869; called by muse, mutect2
- PYGO2 | c.971C>T p.P324L | Missense Mutation (SNP) | VAF 38/606 reads (6%) | SIFT deleterious (0); PolyPhen benign (0.081); catalogued as COSV63757230; called by muse, mutect2
- RAB11FIP3 | c.440G>A p.G147E | Missense Mutation (SNP) | VAF 36/721 reads (5%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.001); catalogued as rs866322889; called by muse, mutect2
- RAB34 | c.487C>T p.L163F | Missense Mutation (SNP) | VAF 26/380 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); catalogued as COSV56386619; called by muse, mutect2
- RASEF | c.1699C>T p.R567* | Nonsense Mutation (SNP) | VAF 26/396 reads (7%) | catalogued as rs1470025089, COSV64586492; called by muse, mutect2
- REG1A | c.339G>A p.W113* | Nonsense Mutation (SNP) | VAF 21/389 reads (5%) | catalogued as COSV52069923; called by muse, mutect2
- RERGL | c.38C>T p.S13F | Missense Mutation (SNP) | VAF 19/283 reads (7%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.255); catalogued as rs865950918, COSV57461008; called by muse, mutect2
- RFX3 | c.1528C>T p.R510C | Missense Mutation (SNP) | VAF 20/424 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as COSV56524622; called by muse, mutect2
- RGS18 | c.673C>T p.Q225* | Nonsense Mutation (SNP) | VAF 22/330 reads (7%) | catalogued as COSV66507132; called by muse, mutect2
- RGS6 | c.460G>A p.E154K | Missense Mutation (SNP) | VAF 12/258 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV59583165, COSV59600322; called by muse, mutect2
- RHBDF2 | c.1550C>T p.S517L | Missense Mutation (SNP) | VAF 28/272 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.481); catalogued as rs1167044584; called by muse, mutect2, varscan2
- RIMS2 | c.4126G>A p.E1376K (on ENST00000666250 / NM_001348490.2; = p.E947K on NM_014677.5 and 7 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 28/505 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.949); catalogued as COSV51718756, COSV99211456; called by muse, mutect2
- RNF113B | c.26G>A p.R9K | Missense Mutation (SNP) | VAF 15/304 reads (5%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as rs1466622537, COSV57435055; called by muse, mutect2
- RNF217 | c.1429C>T p.R477C (on ENST00000521654 / NM_001286398.2; = p.R185C on NM_152553.5) | Missense Mutation (SNP) | VAF 26/424 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1475269973, COSV51575541; called by muse, mutect2
- ROBO2 | c.1271C>A p.P424Q | Missense Mutation (SNP) | VAF 30/378 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV59928993; called by muse, mutect2
- ROBO2 | c.3404G>A p.R1135Q | Missense Mutation (SNP) | VAF 26/538 reads (5%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.454); catalogued as rs879171329, COSV100167812, COSV59929929; called by muse, mutect2
- ROS1 | c.6853G>A p.E2285K | Missense Mutation (SNP) | VAF 29/505 reads (6%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.009); catalogued as rs1442895655, COSV63852551; called by muse, mutect2
- RP1 | c.2621G>A p.G874E | Missense Mutation (SNP) | VAF 19/405 reads (5%) | SIFT tolerated (0.45); PolyPhen benign (0.007); catalogued as COSV55120930; called by muse, mutect2
- RP1L1 | c.3116G>A p.G1039E | Missense Mutation (SNP) | VAF 26/540 reads (5%) | SIFT tolerated (0.16); PolyPhen benign (0.027); catalogued as rs1339683035; called by muse, mutect2
- RRM1 | c.1423C>T p.R475* | Nonsense Mutation (SNP) | VAF 20/320 reads (6%) | catalogued as rs1316694135, COSV100331481; called by muse, mutect2
- RYR3 | c.4808G>A p.R1603Q | Missense Mutation (SNP) | VAF 23/533 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV66779985; called by muse, mutect2
- S100A7 | c.274G>A p.G92R | Missense Mutation (SNP) | VAF 24/489 reads (5%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.9); catalogued as COSV64193052, COSV64193522; called by muse, mutect2
- SAGE1 | c.1514C>T p.S505L | Missense Mutation (SNP) | VAF 21/161 reads (13%) | SIFT tolerated (0.21); PolyPhen benign (0.421); catalogued as COSV61018837; called by muse, mutect2, varscan2
- SALL1 | c.1597C>T p.P533S | Missense Mutation (SNP) | VAF 26/459 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV51758105; called by muse, mutect2
- SAMD3 | c.457C>T p.P153S | Missense Mutation (SNP) | VAF 29/442 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as COSV60776508; called by muse, mutect2
- SCEL | c.1220C>T p.S407F (on ENST00000349847 / NM_144777.3; = p.S387F on NM_003843.4) | Missense Mutation (SNP) | VAF 22/296 reads (7%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.93); catalogued as COSV62992891; called by muse, mutect2
- SCLT1 | c.1367C>T p.S456L | Missense Mutation (SNP) | VAF 40/414 reads (10%) | SIFT deleterious (0); PolyPhen benign (0.022); catalogued as COSV99827641; called by muse, mutect2
- SCN2A | c.5842G>A p.D1948N | Missense Mutation (SNP) | VAF 21/320 reads (7%) | SIFT tolerated (0.09); PolyPhen benign (0.144); catalogued as COSV51834757; called by muse, mutect2
- SCN3A | c.3393+1G>A p.X1131_splice | Splice Site (SNP) | VAF 14/244 reads (6%) | catalogued as COSV51818934; called by muse, mutect2
- SEMA3E | c.1142C>T p.S381F | Missense Mutation (SNP) | VAF 23/204 reads (11%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.703); catalogued as COSV57094602, COSV57096944; called by muse, mutect2, varscan2
- SEMA6B | c.1748G>A p.R583Q | Missense Mutation (SNP) | VAF 32/468 reads (7%) | SIFT tolerated (0.64); PolyPhen benign (0); catalogued as rs1189609989; called by muse, mutect2
- SEZ6 | c.944C>T p.S315F | Missense Mutation (SNP) | VAF 25/601 reads (4%) | SIFT deleterious (0); PolyPhen possibly damaging (0.629); catalogued as rs1279811004; called by muse, mutect2
- SEZ6L | c.2560G>A p.G854R | Missense Mutation (SNP) | VAF 30/449 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1299791158; called by muse, mutect2
- SHPRH | c.2174C>T p.S725F | Missense Mutation (SNP) | VAF 20/412 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV51605320; called by muse, mutect2
- SKIV2L | c.275C>T p.A92V | Missense Mutation (SNP) | VAF 38/756 reads (5%) | SIFT tolerated (0.24); PolyPhen benign (0.007); catalogued as COSV100952873; called by muse, mutect2
- SLC12A3 | c.286G>A p.E96K | Missense Mutation (SNP) | VAF 32/369 reads (9%) | SIFT tolerated (0.3); PolyPhen possibly damaging (0.622); catalogued as rs886052156; ClinVar: uncertain significance; called by muse, mutect2
- SLC13A1 | c.1783C>T p.P595S | Missense Mutation (SNP) | VAF 17/242 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.449); catalogued as COSV52015282, COSV52016444; called by muse, mutect2
- SLC17A1 | c.1253G>A p.G418E | Missense Mutation (SNP) | VAF 19/321 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs868164347, COSV55077981; called by muse, mutect2
- SLC17A6 | c.653C>T p.S218F | Missense Mutation (SNP) | VAF 20/414 reads (5%) | SIFT deleterious (0); PolyPhen benign (0.111); catalogued as COSV99582058; called by muse, mutect2
- SLC26A9 | c.1053G>A p.M351I | Missense Mutation (SNP) | VAF 22/488 reads (5%) | SIFT deleterious (0.02); PolyPhen benign (0.034); catalogued as rs1287882292; called by muse, mutect2
- SLC38A4 | c.415G>A p.E139K | Missense Mutation (SNP) | VAF 16/320 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV56968003; called by muse, mutect2
- SLC46A1 | c.344C>T p.P115L | Missense Mutation (SNP) | VAF 32/593 reads (5%) | SIFT tolerated (0.06); PolyPhen benign (0.391); catalogued as rs976094600; called by muse, mutect2
- SLC46A1 | c.343C>T p.P115S | Missense Mutation (SNP) | VAF 32/590 reads (5%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.526); catalogued as rs1555590959; called by muse, mutect2
- SLC6A19 | c.1477C>T p.P493S | Missense Mutation (SNP) | VAF 43/570 reads (8%) | SIFT tolerated (0.36); PolyPhen possibly damaging (0.838); catalogued as rs776176999, COSV58675527; called by muse, mutect2
- SLITRK3 | c.2183C>T p.S728F | Missense Mutation (SNP) | VAF 22/558 reads (4%) | SIFT deleterious (0.01); PolyPhen benign (0.085); catalogued as COSV53846067; called by muse, mutect2
- SMAD6 | c.1195G>A p.G399S | Missense Mutation (SNP) | VAF 39/540 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56597353; called by muse, mutect2
- SMAD9 | c.347C>T p.P116L | Missense Mutation (SNP) | VAF 32/558 reads (6%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.905); catalogued as rs1472878913, COSV100614982; called by muse, mutect2
- SMAD9 | c.175C>T p.L59F | Missense Mutation (SNP) | VAF 23/561 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV100614576, COSV63205303; called by muse, mutect2
- SMARCA4 | c.4775C>T p.S1592F | Missense Mutation (SNP) | VAF 20/392 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV60803108; called by muse, mutect2
- SNPH | c.517C>T p.Q173* | Nonsense Mutation (SNP) | VAF 24/460 reads (5%) | catalogued as COSV60591003; called by muse, mutect2
- SPATA31E1 | c.3379G>A p.G1127S | Missense Mutation (SNP) | VAF 37/574 reads (6%) | SIFT tolerated (0.77); PolyPhen benign (0.06); catalogued as rs1192194072; called by muse, mutect2
- SPTBN4 | c.7491C>T p.L2497= | Splice Region (SNP) | VAF 16/249 reads (6%) | catalogued as rs1430288994; called by muse, mutect2
- SRCIN1 | c.3128C>T p.P1043L (on ENST00000621492; = p.P1009L on NM_025248.3) | Missense Mutation (SNP) | VAF 36/524 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1341937677; called by muse, mutect2
- ST6GAL2 | c.263C>T p.S88F | Missense Mutation (SNP) | VAF 40/510 reads (8%) | PolyPhen benign (0.135); catalogued as COSV64529701; called by muse, mutect2
- STON2 | c.410C>T p.S137F | Missense Mutation (SNP) | VAF 20/424 reads (5%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.937); catalogued as COSV50844817; called by muse, mutect2
- STYK1 | c.514G>A p.G172R | Missense Mutation (SNP) | VAF 16/394 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as rs1483355413, COSV99030234; called by muse, mutect2
- SV2B | c.44C>T p.P15L | Missense Mutation (SNP) | VAF 22/436 reads (5%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0.01); catalogued as COSV57698634; called by muse, mutect2
- SYNGAP1 | c.1811C>T p.S604L | Missense Mutation (SNP) | VAF 66/692 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV53381539, COSV99537978; called by muse, mutect2
- SZT2 | c.6947C>T p.P2316L (on ENST00000634258 / NM_001365999.1; = p.P2259L on NM_015284.4) | Missense Mutation (SNP) | VAF 32/632 reads (5%) | SIFT tolerated (0.62); PolyPhen benign (0.033); catalogued as rs1325674440; called by muse, mutect2
- TAF1B | c.1423T>G p.F475V | Missense Mutation (SNP) | VAF 21/481 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1484773279; called by muse, mutect2
- TAS2R41 | c.138G>A p.M46I | Missense Mutation (SNP) | VAF 27/490 reads (6%) | SIFT tolerated (0.2); PolyPhen benign (0.34); catalogued as COSV68765004; called by muse, mutect2
- TBC1D1 | c.1807G>A p.E603K | Missense Mutation (SNP) | VAF 40/532 reads (8%) | SIFT tolerated (0.42); PolyPhen benign (0.007); catalogued as rs545868613, COSV54718441; called by muse, mutect2
- TCHHL1 | c.1526C>T p.S509F | Missense Mutation (SNP) | VAF 27/501 reads (5%) | SIFT deleterious (0); PolyPhen benign (0.127); catalogued as rs1208727752; called by muse, mutect2
- TCP11 | c.862C>T p.P288S (on ENST00000512012; = p.P226S on NM_018679.5) | Missense Mutation (SNP) | VAF 44/588 reads (7%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.544); catalogued as rs758259983; called by muse, mutect2
- TDRD15 | c.1064C>T p.S355F | Missense Mutation (SNP) | VAF 22/352 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.953); catalogued as rs1356779687; called by muse, mutect2
- TENM2 | c.478G>A p.E160K | Missense Mutation (SNP) | VAF 13/122 reads (11%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.081); catalogued as rs1343058046, COSV72862591; called by muse, mutect2, varscan2
- THEMIS | c.11C>T p.S4L | Missense Mutation (SNP) | VAF 19/430 reads (4%) | SIFT deleterious (0); PolyPhen benign (0.188); catalogued as COSV100965238; called by muse, mutect2
- TINAG | c.571C>T p.R191C | Missense Mutation (SNP) | VAF 46/490 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.92); catalogued as rs115438249, COSV52508165; called by muse, mutect2
- TLR10 | c.2038G>A p.E680K | Missense Mutation (SNP) | VAF 27/451 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.947); catalogued as rs867756613; called by muse, mutect2
- TLR8 | c.1453G>A p.A485T (on ENST00000218032 / NM_138636.5; = p.A503T on NM_016610.4) | Missense Mutation (SNP) | VAF 15/162 reads (9%) | SIFT tolerated (0.94); PolyPhen possibly damaging (0.485); catalogued as COSV54321371; called by muse, mutect2
- TMC2 | c.565G>A p.E189K | Missense Mutation (SNP) | VAF 22/465 reads (5%) | SIFT tolerated (0.17); PolyPhen benign (0.006); catalogued as COSV62650547, COSV62652488; called by muse, mutect2
- TMEM108 | c.517C>T p.R173* | Nonsense Mutation (SNP) | VAF 30/482 reads (6%) | catalogued as rs1381522961; called by muse, mutect2
- TMEM108 | c.886G>A p.G296R | Missense Mutation (SNP) | VAF 34/550 reads (6%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0); catalogued as COSV100419334; called by muse, mutect2
- TMEM132B | c.2348G>A p.G783E | Missense Mutation (SNP) | VAF 30/427 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as COSV54754134; called by muse, mutect2
- TMEM212 | c.379C>T p.P127S | Missense Mutation (SNP) | VAF 18/339 reads (5%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.75); catalogued as rs868268712; called by muse, mutect2
- TMEM235 | c.488G>A p.G163D | Missense Mutation (SNP) | VAF 44/570 reads (8%) | SIFT tolerated (0.22); PolyPhen benign (0.294); catalogued as rs1339245518; called by muse, mutect2
- TMPRSS4 | c.1011G>A p.G337= | Splice Region (SNP) | VAF 16/322 reads (5%) | catalogued as rs1173419237, COSV71109845; called by muse, mutect2
- TNC | c.4876C>T p.L1626F | Missense Mutation (SNP) | VAF 20/365 reads (5%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.521); catalogued as COSV60781240; called by muse, mutect2
- TPSAB1 | c.181G>A p.G61S | Missense Mutation (SNP) | VAF 42/848 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1290918324, COSV58783373; called by muse, mutect2
- TRAF1 | c.658C>T p.H220Y | Missense Mutation (SNP) | VAF 33/414 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.579); catalogued as COSV65868612; called by muse, mutect2
- TRANK1 | c.7429G>A p.D2477N | Missense Mutation (SNP) | VAF 28/518 reads (5%) | SIFT tolerated (0.6); PolyPhen benign (0); catalogued as COSV100081392; called by muse, mutect2
- TRAV29DV5 | c.202G>A p.E68K | Missense Mutation (SNP) | VAF 14/196 reads (7%) | SIFT tolerated (1); PolyPhen benign (0.007); catalogued as rs1282840676; called by muse, mutect2
- TRIM39 | c.980C>T p.A327V | Missense Mutation (SNP) | VAF 33/472 reads (7%) | SIFT tolerated (0.37); PolyPhen benign (0.003); catalogued as rs765751274; called by muse, mutect2
- TRPC5 | c.1261G>A p.E421K | Missense Mutation (SNP) | VAF 16/169 reads (9%) | SIFT deleterious (0.01); PolyPhen benign (0.403); catalogued as rs866964490, COSV53284904; called by muse, mutect2
- TRPM4 | c.1124C>T p.T375I | Missense Mutation (SNP) | VAF 16/320 reads (5%) | SIFT tolerated (0.05); PolyPhen benign (0.124); catalogued as rs1197042883, COSV53264828; called by muse, mutect2
- TRPM6 | c.44C>T p.S15F | Missense Mutation (SNP) | VAF 16/252 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.947); catalogued as COSV100666264; called by muse, mutect2
- TTBK1 | c.422C>T p.S141F | Missense Mutation (SNP) | VAF 45/660 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV52493255; called by muse, mutect2
- TTC37 | c.460G>A p.E154K | Missense Mutation (SNP) | VAF 36/456 reads (8%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV62455295; called by muse, mutect2
- TTC6 | c.1501G>A p.D501N | Missense Mutation (SNP) | VAF 18/381 reads (5%) | SIFT tolerated (0.59); PolyPhen benign (0.028); catalogued as rs1395484872; called by muse, mutect2
- TTN | c.85783G>A p.E28595K (on ENST00000591111; = p.E21171K on NM_003319.4) | Missense Mutation (SNP) | VAF 27/478 reads (6%) | PolyPhen probably damaging (0.994); catalogued as rs974510652; called by muse, mutect2
- TTN | c.72536C>T p.P24179L (on ENST00000591111; = p.P16755L on NM_003319.4) | Missense Mutation (SNP) | VAF 38/514 reads (7%) | PolyPhen probably damaging (0.913); catalogued as COSV100609978, COSV59955321; called by muse, mutect2
- TTN | c.56069G>A p.R18690K (on ENST00000591111; = p.R11266K on NM_003319.4) | Missense Mutation (SNP) | VAF 20/343 reads (6%) | PolyPhen benign (0.003); catalogued as COSV60048662; called by muse, mutect2
- TTN | c.53576C>T p.S17859F (on ENST00000591111; = p.S10435F on NM_003319.4) | Missense Mutation (SNP) | VAF 33/501 reads (7%) | PolyPhen probably damaging (0.998); catalogued as rs1465284889; called by muse, mutect2
- TTN | c.39521G>A p.G13174E (on ENST00000591111; = p.G5750E on NM_003319.4) | Missense Mutation (SNP) | VAF 18/268 reads (7%) | PolyPhen probably damaging (0.959); catalogued as rs1157011423, COSV60041104, COSV60280736; called by muse, mutect2
- TTN | c.27433G>A p.G9145R (on ENST00000591111; = p.G8218R on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 28/436 reads (6%) | PolyPhen possibly damaging (0.788); catalogued as COSV59903187; called by muse, mutect2
- TTN | c.19168G>A p.E6390K (on ENST00000591111; = p.E5463K on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 32/530 reads (6%) | PolyPhen benign (0.04); catalogued as COSV60108334; called by muse, mutect2
- TTN | c.5749C>T p.P1917S (on ENST00000591111; = p.P1871S on NM_003319.4) | Missense Mutation (SNP) | VAF 24/409 reads (6%) | PolyPhen probably damaging (0.998); catalogued as COSV59897085; called by muse, mutect2
- TTN | c.5077G>A p.D1693N (on ENST00000591111; = p.D1647N on NM_003319.4) | Missense Mutation (SNP) | VAF 28/580 reads (5%) | PolyPhen probably damaging (0.998); catalogued as COSV60274738; called by muse, mutect2
- UGT2B11 | c.687G>A p.M229I | Missense Mutation (SNP) | VAF 14/246 reads (6%) | SIFT tolerated (0.4); PolyPhen benign (0); catalogued as COSV71424442; called by muse, mutect2
- UGT2B11 | c.117G>A p.M39I | Missense Mutation (SNP) | VAF 16/423 reads (4%) | SIFT tolerated (0.84); PolyPhen benign (0.007); catalogued as COSV71423416; called by muse, mutect2
- UGT2B17 | c.273G>A p.M91I | Missense Mutation (SNP) | VAF 13/211 reads (6%) | SIFT tolerated (0.22); PolyPhen benign (0); catalogued as rs1351493392, COSV58500798; called by muse, mutect2
- UGT2B4 | c.1306C>T p.P436S | Missense Mutation (SNP) | VAF 12/189 reads (6%) | SIFT tolerated (0.16); PolyPhen probably damaging (0.922); catalogued as COSV59318327; called by muse, mutect2
- UGT8 | c.1327C>T p.R443* | Nonsense Mutation (SNP) | VAF 24/379 reads (6%) | catalogued as COSV60416822; called by muse, mutect2
- UNC13C | c.6535G>A p.E2179K | Missense Mutation (SNP) | VAF 20/430 reads (5%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.081); catalogued as COSV99517563; called by muse, mutect2
- UNC5A | c.487G>A p.E163K | Missense Mutation (SNP) | VAF 23/465 reads (5%) | SIFT tolerated (0.09); PolyPhen benign (0.14); catalogued as rs1163060164, COSV56166079; called by muse, mutect2
- USP26 | c.1412G>A p.R471K | Missense Mutation (SNP) | VAF 23/215 reads (11%) | SIFT tolerated (0.09); PolyPhen benign (0.015); catalogued as COSV63708348, COSV63709382; called by muse, mutect2, varscan2
- USP6 | c.1450C>T p.Q484* | Nonsense Mutation (SNP) | VAF 23/474 reads (5%) | catalogued as rs1209155230; called by muse, mutect2
- VEGFC | c.1199C>T p.S400L | Missense Mutation (SNP) | VAF 20/389 reads (5%) | SIFT tolerated (0.33); PolyPhen benign (0.007); catalogued as COSV54595583; called by muse, mutect2
- VWA3B | c.1928G>A p.R643K | Missense Mutation (SNP) | VAF 25/480 reads (5%) | SIFT tolerated (1); PolyPhen benign (0.005); catalogued as COSV101345898; called by muse, mutect2
- WDR18 | c.650C>T p.S217F | Missense Mutation (SNP) | VAF 20/540 reads (4%) | SIFT deleterious (0.02); PolyPhen benign (0.079); catalogued as COSV99242764; called by muse, mutect2
- WDR87 | c.7601G>A p.R2534Q | Missense Mutation (SNP) | VAF 20/476 reads (4%) | SIFT tolerated (0.43); PolyPhen benign (0.021); catalogued as rs1490878605, COSV58200849; called by muse, mutect2
- WDR87 | c.5987G>A p.R1996K | Missense Mutation (SNP) | VAF 17/335 reads (5%) | SIFT tolerated (0.52); PolyPhen benign (0.061); catalogued as COSV58204841; called by muse, mutect2
- WDR87 | c.991C>T p.R331W | Missense Mutation (SNP) | VAF 20/338 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); catalogued as rs1207656862, COSV58200142; called by muse, mutect2
- WIPF3 | c.583C>T p.P195S | Missense Mutation (SNP) | VAF 28/309 reads (9%) | SIFT tolerated, low confidence (0.29); PolyPhen probably damaging (0.992); catalogued as COSV99078754; called by muse, mutect2
- WNK1 | c.457C>T p.P153S | Missense Mutation (SNP) | VAF 30/644 reads (5%) | SIFT tolerated (0.23); PolyPhen benign (0.003); catalogued as COSV60036854; called by muse, mutect2
- WWC2 | c.1807C>T p.Q603* | Nonsense Mutation (SNP) | VAF 25/361 reads (7%) | catalogued as COSV66713336; called by muse, mutect2
- ZAN | c.1174G>A p.G392S | Missense Mutation (SNP) | VAF 28/535 reads (5%) | SIFT tolerated (0.33); PolyPhen possibly damaging (0.77); catalogued as COSV61805686; called by muse, mutect2
- ZBED9 | c.2655G>A p.M885I | Missense Mutation (SNP) | VAF 49/524 reads (9%) | SIFT tolerated (0.97); PolyPhen possibly damaging (0.708); catalogued as COSV71729308; called by muse, mutect2
- ZC3H4 | c.3632C>T p.P1211L | Missense Mutation (SNP) | VAF 46/742 reads (6%) | SIFT deleterious (0.01); PolyPhen benign (0.003); catalogued as COSV99452175; called by muse, mutect2
- ZFHX3 | c.5870T>C p.V1957A | Missense Mutation (SNP) | VAF 20/498 reads (4%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.978); catalogued as COSV51713334; called by muse, mutect2
- ZFP42 | c.320C>T p.S107F | Missense Mutation (SNP) | VAF 22/420 reads (5%) | SIFT deleterious (0); PolyPhen possibly damaging (0.753); catalogued as COSV100479136, COSV58816339; called by muse, mutect2
- ZIC4 | c.620C>T p.P207L | Missense Mutation (SNP) | VAF 18/402 reads (4%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.992); catalogued as COSV67171724; called by muse, mutect2
- ZNF135 | c.736G>A p.E246K (on ENST00000313434 / NM_001289401.2; = p.E258K on NM_003436.4) | Missense Mutation (SNP) | VAF 30/608 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as rs1439743316; called by muse, mutect2
- ZNF232 | c.973C>T p.H325Y | Missense Mutation (SNP) | VAF 17/367 reads (5%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.99); catalogued as COSV51504568; called by muse, mutect2
- ZNF470 | c.2095C>T p.H699Y | Missense Mutation (SNP) | VAF 27/462 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.82); catalogued as COSV57970353; called by muse, mutect2
- ZNF479 | c.509C>T p.S170L | Missense Mutation (SNP) | VAF 15/177 reads (8%) | SIFT tolerated (0.17); PolyPhen benign (0.001); catalogued as COSV58643490, COSV58644349; called by muse, mutect2
- ZNF596 | c.1441G>A p.G481R | Missense Mutation (SNP) | VAF 18/386 reads (5%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as COSV57655146; called by muse, mutect2
- ZNF628 | c.1994C>T p.P665L | Missense Mutation (SNP) | VAF 38/762 reads (5%) | SIFT tolerated (0.21); PolyPhen benign (0); catalogued as rs1349321009, COSV52701434; called by muse, mutect2
- ZNF700 | c.1211C>T p.S404F | Missense Mutation (SNP) | VAF 32/414 reads (8%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.989); catalogued as rs1212766672, COSV54315279; called by muse, mutect2
- ZNF804A | c.331G>A p.E111K | Missense Mutation (SNP) | VAF 24/320 reads (8%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.631); catalogued as COSV100166311; called by muse, mutect2
- ZNF831 | c.2266G>A p.E756K | Missense Mutation (SNP) | VAF 42/552 reads (8%) | SIFT tolerated (0.09); PolyPhen benign (0.236); catalogued as rs754300464, COSV64042106; called by muse, mutect2
- ZNF844 | c.1468C>T p.P490S | Missense Mutation (SNP) | VAF 24/644 reads (4%) | SIFT tolerated (0.42); PolyPhen benign (0.009); catalogued as COSV71518660; called by muse, mutect2
- ABCB5 | c.2228G>A p.G743D (on ENST00000404938 / NM_001163941.2; = p.G298D on NM_178559.6) | Missense Mutation (SNP) | VAF 19/251 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.924); called by muse, mutect2
- ABCG4 | c.76G>A p.D26N | Missense Mutation (SNP) | VAF 31/599 reads (5%) | SIFT tolerated (0.28); PolyPhen benign (0.025); called by muse, mutect2
- AC024598.1 | c.1349G>A p.G450D | Missense Mutation (SNP) | VAF 20/334 reads (6%) | SIFT tolerated, low confidence (0.43); PolyPhen benign (0); called by muse, mutect2
- ACSBG1 | c.1138G>A p.E380K | Missense Mutation (SNP) | VAF 26/608 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- ACTL7B | c.1166C>T p.S389F | Missense Mutation (SNP) | VAF 32/464 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- ADCY1 | c.3040G>A p.V1014I | Missense Mutation (SNP) | VAF 27/330 reads (8%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.592); called by muse, mutect2
- ADCY8 | c.2911G>A p.E971K | Missense Mutation (SNP) | VAF 21/266 reads (8%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.883); called by muse, mutect2
- ADGRB1 | c.4735G>A p.D1579N | Missense Mutation (SNP) | VAF 32/398 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2
- ADGRG6 | c.3473G>A p.G1158E | Missense Mutation (SNP) | VAF 24/388 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- AGAP1 | c.746C>T p.S249F | Missense Mutation (SNP) | VAF 24/427 reads (6%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.982); called by muse, mutect2
- AGBL1 | c.2956G>A p.E986K | Missense Mutation (SNP) | VAF 16/364 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- AKAP12 | c.3106G>A p.E1036K | Missense Mutation (SNP) | VAF 30/502 reads (6%) | SIFT tolerated (0.23); PolyPhen benign (0.024); called by muse, mutect2
- AKAP12 | c.3107A>T p.E1036V | Missense Mutation (SNP) | VAF 28/502 reads (6%) | SIFT deleterious (0.05); PolyPhen benign (0.113); called by muse, mutect2
- AKAP4 | c.1035G>A p.M345I | Missense Mutation (SNP) | VAF 31/286 reads (11%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.95); called by muse, mutect2, varscan2
- AL353579.1 | c.3G>A p.M1? | Translation Start Site (SNP) | VAF 26/371 reads (7%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.895); called by muse, mutect2
- ALPI | c.476G>A p.G159E | Missense Mutation (SNP) | VAF 14/326 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- AMHR2 | c.437G>A p.W146* | Nonsense Mutation (SNP) | VAF 26/408 reads (6%) | called by muse, mutect2
- AMPD1 | c.2234G>A p.G745E | Missense Mutation (SNP) | VAF 20/387 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- ANKHD1-EIF4EBP3 | c.5087G>A p.R1696K | Missense Mutation (SNP) | VAF 17/250 reads (7%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.931); called by muse, mutect2
- ANKRD31 | c.5251G>A p.D1751N | Missense Mutation (SNP) | VAF 24/494 reads (5%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.978); called by muse, mutect2
- ANKRD31 | c.4363G>A p.E1455K | Missense Mutation (SNP) | VAF 30/434 reads (7%) | SIFT tolerated (0.13); PolyPhen benign (0.365); called by muse, mutect2
- ANXA10 | c.41C>T p.A14V | Missense Mutation (SNP) | VAF 19/446 reads (4%) | SIFT tolerated (0.46); PolyPhen benign (0.005); called by muse, mutect2
- APBA1 | c.603A>G p.I201M | Missense Mutation (SNP) | VAF 44/610 reads (7%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.459); called by muse, mutect2
- ARHGAP35 | c.1207C>T p.P403S | Missense Mutation (SNP) | VAF 24/492 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- ARHGEF9 | c.1396C>T p.P466S | Missense Mutation (SNP) | VAF 29/192 reads (15%) | SIFT deleterious (0.01); PolyPhen benign (0.012); called by muse, mutect2, varscan2
- ARID5B | c.2882C>T p.T961I | Missense Mutation (SNP) | VAF 18/410 reads (4%) | SIFT deleterious (0); PolyPhen possibly damaging (0.722); called by muse, mutect2
- ASB10 | c.625G>A p.G209S (on ENST00000420175 / NM_001142459.2; = p.G194S on NM_080871.4) | Missense Mutation (SNP) | VAF 34/397 reads (9%) | SIFT tolerated (0.51); PolyPhen probably damaging (0.974); called by muse, mutect2
- ATF7IP2 | c.1340C>T p.S447F | Missense Mutation (SNP) | VAF 12/191 reads (6%) | SIFT tolerated (0.83); PolyPhen benign (0.003); called by muse, mutect2
- ATP8A1 | c.3284G>A p.G1095E | Missense Mutation (SNP) | VAF 18/434 reads (4%) | SIFT tolerated (0.24); PolyPhen benign (0.031); called by muse, mutect2
- ATRX | c.3931C>T p.P1311S | Missense Mutation (SNP) | VAF 12/105 reads (11%) | SIFT tolerated (0.68); PolyPhen benign (0); called by muse, mutect2, varscan2
- ATXN2 | c.3695A>G p.H1232R (on ENST00000550104; = p.H1072R on NM_002973.4) | Missense Mutation (SNP) | VAF 32/468 reads (7%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.549); called by muse, mutect2
- BACH2 | c.2252C>T p.A751V | Missense Mutation (SNP) | VAF 30/506 reads (6%) | SIFT tolerated (0.42); PolyPhen benign (0); called by muse, mutect2
- BBS2 | c.1295C>T p.P432L | Missense Mutation (SNP) | VAF 36/504 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- BCL11B | c.2633G>A p.G878D (on ENST00000357195 / NM_001282237.2; = p.G807D on NM_022898.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 25/409 reads (6%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.889); called by muse, mutect2
- BRD7 | c.1450C>T p.P484S | Missense Mutation (SNP) | VAF 24/424 reads (6%) | SIFT tolerated (0.7); PolyPhen benign (0.192); called by muse, mutect2
- BRINP1 | c.1195G>A p.E399K | Missense Mutation (SNP) | VAF 15/329 reads (5%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.956); called by muse, mutect2
- BRWD3 | c.1655C>T p.P552L | Missense Mutation (SNP) | VAF 14/116 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.945); called by muse, mutect2, varscan2
- BTN1A1 | c.1069A>T p.R357W | Missense Mutation (SNP) | VAF 28/705 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); called by muse, mutect2
- C16orf92 | c.293C>T p.S98F | Missense Mutation (SNP) | VAF 18/358 reads (5%) | SIFT tolerated (0.1); PolyPhen benign (0.169); called by muse, mutect2
- C1QC | c.34G>A p.G12R | Missense Mutation (SNP) | VAF 29/632 reads (5%) | SIFT tolerated (0.74); PolyPhen benign (0.181); called by muse, mutect2
- C20orf203 | c.287G>A p.R96K | Missense Mutation (SNP) | VAF 16/385 reads (4%) | SIFT tolerated, low confidence (0.51); PolyPhen benign (0.146); called by muse, mutect2
- C2CD6 | c.101C>T p.P34L | Missense Mutation (SNP) | VAF 24/448 reads (5%) | SIFT deleterious (0.01); PolyPhen benign (0.005); called by muse, mutect2
- C2orf16 | c.2845G>A p.G949R | Missense Mutation (SNP) | VAF 13/348 reads (4%) | SIFT tolerated (0.23); PolyPhen benign (0.439); called by muse, mutect2
- C3orf20 | c.1943G>A p.G648E | Missense Mutation (SNP) | VAF 20/375 reads (5%) | SIFT tolerated (0.32); PolyPhen possibly damaging (0.466); called by muse, mutect2
- CABIN1 | c.6082C>T p.P2028S | Missense Mutation (SNP) | VAF 41/560 reads (7%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0.024); called by muse, mutect2
- CACNA1G | c.3970G>A p.E1324K | Missense Mutation (SNP) | VAF 22/368 reads (6%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.951); called by muse, mutect2
- CACNA2D3 | c.644G>A p.G215E | Missense Mutation (SNP) | VAF 18/233 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- CACNG4 | c.799G>A p.G267R | Missense Mutation (SNP) | VAF 53/572 reads (9%) | SIFT deleterious (0.04); PolyPhen benign (0.049); called by muse, mutect2
- CADPS2 | c.1637C>T p.T546I | Missense Mutation (SNP) | VAF 34/273 reads (12%) | SIFT tolerated (0.43); PolyPhen benign (0.195); called by muse, mutect2, varscan2
- CARD11 | c.2695C>T p.L899F | Missense Mutation (SNP) | VAF 49/388 reads (13%) | SIFT deleterious (0.05); PolyPhen benign (0.071); called by muse, mutect2
- CARD19 | c.170C>T p.S57F | Missense Mutation (SNP) | VAF 25/425 reads (6%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.838); called by muse, mutect2
- CATSPER1 | c.299C>T p.P100L | Missense Mutation (SNP) | VAF 38/626 reads (6%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.831); called by muse, mutect2
- CBX1 | c.496G>A p.E166K | Missense Mutation (SNP) | VAF 25/425 reads (6%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.989); called by muse, mutect2
- CCDC168 | c.17154G>A p.M5718I | Missense Mutation (SNP) | VAF 16/366 reads (4%) | SIFT tolerated (0.06); PolyPhen benign (0.206); called by muse, mutect2
- CCDC168 | c.9130C>T p.H3044Y | Missense Mutation (SNP) | VAF 23/420 reads (5%) | SIFT tolerated (0.08); PolyPhen benign (0.014); called by muse, mutect2
- CCDC168 | c.4781G>A p.G1594E | Missense Mutation (SNP) | VAF 24/534 reads (4%) | SIFT tolerated (0.49); PolyPhen benign (0.191); called by muse, mutect2
- CCDC172 | c.427C>T p.Q143* | Nonsense Mutation (SNP) | VAF 12/183 reads (7%) | called by muse, mutect2
- CCDC18 | c.217C>T p.P73S | Missense Mutation (SNP) | VAF 18/416 reads (4%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2
- CCDC60 | c.1227G>A p.M409I | Missense Mutation (SNP) | VAF 16/232 reads (7%) | SIFT tolerated (0.43); PolyPhen benign (0.053); called by muse, mutect2
- CD163 | c.729G>A p.W243* | Nonsense Mutation (SNP) | VAF 18/424 reads (4%) | called by muse, mutect2
- CD5 | c.320G>A p.C107Y | Missense Mutation (SNP) | VAF 36/448 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2
- CDH13 | c.1234G>A p.E412K | Missense Mutation (SNP) | VAF 23/512 reads (4%) | SIFT tolerated (0.17); PolyPhen benign (0.306); called by muse, mutect2
- CDH17 | c.1600G>A p.E534K | Missense Mutation (SNP) | VAF 16/450 reads (4%) | SIFT tolerated (0.24); PolyPhen benign (0.257); called by muse, mutect2
- CDH6 | c.52C>T p.P18S | Missense Mutation (SNP) | VAF 20/453 reads (4%) | SIFT tolerated (0.51); PolyPhen benign (0.012); called by muse, mutect2
- CDHR5 | c.1986G>A p.M662I (on ENST00000358353 / NM_001171968.2; = p.M668I on NM_021924.5) | Missense Mutation (SNP) | VAF 40/747 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); called by muse, mutect2
- CDON | c.2440C>T p.Q814* | Nonsense Mutation (SNP) | VAF 38/483 reads (8%) | called by muse, mutect2
- CDRT1 | c.1051C>T p.P351S | Missense Mutation (SNP) | VAF 16/330 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2
- CEACAM20 | c.1594C>T p.P532S | Missense Mutation (SNP) | VAF 28/390 reads (7%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); called by muse, mutect2
- CEP192 | c.2999C>T p.S1000F | Missense Mutation (SNP) | VAF 17/331 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); called by muse, mutect2
- CFAP46 | c.4226C>T p.A1409V | Missense Mutation (SNP) | VAF 19/338 reads (6%) | SIFT tolerated (0.26); PolyPhen benign (0.003); called by muse, mutect2
- CFAP52 | c.1292G>A p.R431K | Missense Mutation (SNP) | VAF 22/412 reads (5%) | SIFT tolerated (0.13); PolyPhen benign (0.237); called by muse, mutect2
- CFAP58 | c.1952A>T p.D651V | Missense Mutation (SNP) | VAF 19/525 reads (4%) | SIFT deleterious (0); PolyPhen possibly damaging (0.837); called by muse, mutect2
- CHADL | c.1238G>A p.G413D | Missense Mutation (SNP) | VAF 48/532 reads (9%) | SIFT tolerated (0.38); PolyPhen benign (0.212); called by muse, mutect2
- CHAF1A | c.2378C>T p.P793L | Missense Mutation (SNP) | VAF 38/662 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- CHD7 | c.6422C>T p.S2141F | Missense Mutation (SNP) | VAF 24/384 reads (6%) | SIFT deleterious (0.01); PolyPhen benign (0.285); called by muse, mutect2
- CHRNB4 | c.1247C>T p.S416F | Missense Mutation (SNP) | VAF 28/463 reads (6%) | SIFT deleterious (0.01); PolyPhen benign (0.195); called by muse, mutect2
- CHST4 | c.181C>T p.L61F | Missense Mutation (SNP) | VAF 42/572 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); called by muse, mutect2
- CHST4 | c.424C>T p.P142S | Missense Mutation (SNP) | VAF 27/507 reads (5%) | SIFT tolerated (0.4); PolyPhen benign (0.034); called by muse, mutect2
- CLEC20A | c.436C>T p.L146F | Missense Mutation (SNP) | VAF 19/518 reads (4%) | SIFT tolerated (0.75); PolyPhen possibly damaging (0.818); called by muse, mutect2
- CLEC4D | c.190C>T p.L64F | Missense Mutation (SNP) | VAF 24/364 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.521); called by muse, mutect2
- CLIC6 | c.98C>T p.A33V | Missense Mutation (SNP) | VAF 53/713 reads (7%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.023); called by muse, mutect2
- CLIP1 | c.767C>T p.A256V | Missense Mutation (SNP) | VAF 18/314 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2
- CMPK2 | c.407C>T p.P136L | Missense Mutation (SNP) | VAF 40/644 reads (6%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); called by muse, mutect2
- CMYA5 | c.5294G>A p.G1765E | Missense Mutation (SNP) | VAF 26/486 reads (5%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); called by muse, mutect2
- CNTN1 | c.2408C>T p.S803L | Missense Mutation (SNP) | VAF 18/270 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.947); called by muse, mutect2
- COL14A1 | c.4456-1G>A p.X1486_splice | Splice Site (SNP) | VAF 15/289 reads (5%) | called by muse, mutect2
- COL3A1 | c.353G>A p.G118E | Missense Mutation (SNP) | VAF 17/289 reads (6%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); called by muse, mutect2
- COL4A4 | c.502G>A p.E168K | Missense Mutation (SNP) | VAF 25/318 reads (8%) | SIFT tolerated (0.27); PolyPhen benign (0.007); called by muse, mutect2
- COL5A3 | c.3041C>T p.P1014L | Missense Mutation (SNP) | VAF 28/542 reads (5%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.895); called by muse, mutect2
- COL5A3 | c.1201G>A p.G401R | Missense Mutation (SNP) | VAF 24/440 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- COL7A1 | c.4333G>A p.G1445R | Missense Mutation (SNP) | VAF 38/540 reads (7%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.999); called by muse, mutect2
- COL9A1 | c.2548C>T p.P850S | Missense Mutation (SNP) | VAF 34/476 reads (7%) | SIFT tolerated (0.1); PolyPhen benign (0.25); called by muse, mutect2
- COL9A2 | c.383G>A p.G128D | Missense Mutation (SNP) | VAF 23/372 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); called by muse, mutect2
- COX4I2 | c.460C>T p.P154S | Missense Mutation (SNP) | VAF 23/467 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- CSNK2A1 | c.59C>T p.P20L | Missense Mutation (SNP) | VAF 18/362 reads (5%) | SIFT deleterious (0); PolyPhen possibly damaging (0.706); called by muse, mutect2
- CTTNBP2NL | c.1414C>T p.Q472* | Nonsense Mutation (SNP) | VAF 30/541 reads (6%) | called by muse, mutect2
- CXCL9 | c.208G>A p.G70R | Missense Mutation (SNP) | VAF 23/364 reads (6%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.874); called by muse, mutect2
- CXorf21 | c.563G>A p.W188* | Nonsense Mutation (SNP) | VAF 32/274 reads (12%) | called by muse, mutect2, varscan2
- CYP2E1 | c.1004C>T p.P335L | Missense Mutation (SNP) | VAF 24/392 reads (6%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.956); called by muse, mutect2
- CYP4F2 | c.1499G>A p.R500K | Missense Mutation (SNP) | VAF 33/648 reads (5%) | SIFT tolerated (0.11); PolyPhen probably damaging (1); called by muse, mutect2
- DCHS2 | c.767G>A p.R256Q | Missense Mutation (SNP) | VAF 42/536 reads (8%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); called by muse, mutect2
- DCN | c.592G>A p.G198R | Missense Mutation (SNP) | VAF 24/339 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- DDB2 | c.1130G>A p.G377E | Missense Mutation (SNP) | VAF 18/402 reads (4%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.986); called by muse, mutect2
- DDX59 | c.217C>T p.H73Y | Missense Mutation (SNP) | VAF 44/486 reads (9%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0.003); called by muse, mutect2
- DELE1 | c.211C>T p.Q71* | Nonsense Mutation (SNP) | VAF 17/392 reads (4%) | called by muse, mutect2
- DENND11 | c.475C>T p.P159S | Missense Mutation (SNP) | VAF 70/559 reads (13%) | SIFT tolerated (0.17); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- DGAT2L6 | c.442C>T p.P148S | Missense Mutation (SNP) | VAF 21/188 reads (11%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- DHX37 | c.653C>T p.P218L | Missense Mutation (SNP) | VAF 26/496 reads (5%) | SIFT tolerated (0.24); PolyPhen benign (0); called by muse, mutect2
- DHX37 | c.652C>T p.P218S | Missense Mutation (SNP) | VAF 26/496 reads (5%) | SIFT tolerated (0.87); PolyPhen benign (0.007); called by muse, mutect2
- DLEC1 | c.1892G>A p.R631K | Missense Mutation (SNP) | VAF 26/436 reads (6%) | SIFT tolerated (0.36); PolyPhen benign (0.001); called by muse, mutect2
- DLG1 | c.365C>T p.S122F | Missense Mutation (SNP) | VAF 21/355 reads (6%) | SIFT tolerated, low confidence (0.13); PolyPhen possibly damaging (0.675); called by muse, mutect2
- DLGAP3 | c.182G>A p.G61E | Missense Mutation (SNP) | VAF 36/646 reads (6%) | SIFT tolerated (0.07); PolyPhen benign (0.122); called by muse, mutect2
- DLGAP3 | c.181G>A p.G61R | Missense Mutation (SNP) | VAF 36/647 reads (6%) | SIFT tolerated (0.08); PolyPhen benign (0.001); called by muse, mutect2
- DMBT1 | c.1784G>A p.G595E | Missense Mutation (SNP) | VAF 18/420 reads (4%) | SIFT tolerated (0.21); PolyPhen benign (0.006); called by muse, mutect2
- DMBT1 | c.6913C>T p.P2305S (on ENST00000338354 / NM_001377530.1; = p.P1548S on NM_004406.3) | Missense Mutation (SNP) | VAF 17/442 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- DMD | c.10084C>T p.P3362S | Missense Mutation (SNP) | VAF 14/162 reads (9%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.918); called by muse, mutect2
- DMD | c.136G>A p.D46N | Missense Mutation (SNP) | VAF 31/208 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- DNAH1 | c.203C>T p.P68L | Missense Mutation (SNP) | VAF 23/556 reads (4%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0); called by muse, mutect2
- DNAH17 | c.3197G>A p.C1066Y | Missense Mutation (SNP) | VAF 43/413 reads (10%) | SIFT tolerated (0.26); PolyPhen probably damaging (0.947); called by muse, mutect2, varscan2
- DNAH2 | c.12928G>A p.E4310K | Missense Mutation (SNP) | VAF 28/484 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); called by muse, mutect2
- DNAH5 | c.10231A>G p.K3411E | Missense Mutation (SNP) | VAF 22/420 reads (5%) | SIFT tolerated (0.47); PolyPhen benign (0.014); called by muse, mutect2
- DNAH6 | c.2337G>A p.M779I | Missense Mutation (SNP) | VAF 32/502 reads (6%) | SIFT tolerated (0.13); PolyPhen benign (0.003); called by muse, mutect2
- DNAH6 | c.4681G>A p.E1561K | Missense Mutation (SNP) | VAF 26/351 reads (7%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.665); called by muse, mutect2
- DNM3 | c.1054G>A p.D352N | Missense Mutation (SNP) | VAF 41/498 reads (8%) | SIFT tolerated (0.27); PolyPhen possibly damaging (0.9); called by muse, mutect2
- DRD2 | c.488C>T p.S163F | Missense Mutation (SNP) | VAF 24/491 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2
- DSP | c.8218G>A p.E2740K | Missense Mutation (SNP) | VAF 40/548 reads (7%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.992); called by muse, mutect2
- DST | c.6791C>T p.T2264I | Missense Mutation (SNP) | VAF 27/317 reads (9%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.116); called by muse, mutect2
- EBLN1 | c.952G>A p.G318R | Missense Mutation (SNP) | VAF 30/478 reads (6%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); called by muse, mutect2
- EFCAB6 | c.3883C>T p.P1295S | Missense Mutation (SNP) | VAF 25/283 reads (9%) | SIFT tolerated (0.16); PolyPhen benign (0.056); called by muse, mutect2
- EFCAB8 | c.967C>T p.P323S | Missense Mutation (SNP) | VAF 12/248 reads (5%) | SIFT tolerated (0.71); PolyPhen benign (0.003); called by muse, mutect2
- EFHC2 | c.1471G>A p.G491R | Missense Mutation (SNP) | VAF 18/252 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.898); called by muse, mutect2
- EFL1 | c.3266A>T p.K1089M | Missense Mutation (SNP) | VAF 26/466 reads (6%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.924); called by muse, mutect2
- EGFL6 | c.1324C>T p.H442Y | Missense Mutation (SNP) | VAF 24/260 reads (9%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.653); called by muse, mutect2
- EIF2S3B | c.392C>T p.S131F | Missense Mutation (SNP) | VAF 27/495 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); called by muse, mutect2
- ELOA2 | c.313G>A p.D105N | Missense Mutation (SNP) | VAF 38/632 reads (6%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.644); called by muse, mutect2
- EPHB2 | c.377C>T p.T126I | Missense Mutation (SNP) | VAF 28/476 reads (6%) | SIFT tolerated (0.56); PolyPhen benign (0.014); called by muse, mutect2
- EPS8 | c.1829G>A p.R610K | Missense Mutation (SNP) | VAF 23/334 reads (7%) | SIFT tolerated (0.72); PolyPhen benign (0); called by muse, mutect2
- ERICH3 | c.235G>A p.D79N | Missense Mutation (SNP) | VAF 13/206 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, mutect2
- ERVFRD-1 | c.1159G>A p.E387K | Missense Mutation (SNP) | VAF 26/399 reads (7%) | SIFT tolerated (0.22); PolyPhen benign (0.398); called by muse, mutect2
- ERVV-2 | c.1036G>A p.D346N | Missense Mutation (SNP) | VAF 17/494 reads (3%) | SIFT deleterious (0.05); PolyPhen benign (0.062); called by muse, mutect2
- ESPNL | c.613G>A p.G205S | Missense Mutation (SNP) | VAF 29/533 reads (5%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.96); called by muse, mutect2
- EZH2 | c.494T>A p.F165Y | Missense Mutation (SNP) | VAF 20/306 reads (7%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.731); called by muse, mutect2
- EZHIP | c.344C>T p.P115L | Missense Mutation (SNP) | VAF 25/242 reads (10%) | SIFT tolerated (0.07); PolyPhen benign (0.05); called by muse, mutect2, varscan2
- F10 | c.343G>A p.G115R | Missense Mutation (SNP) | VAF 29/387 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- FAM160A2 | c.470C>T p.T157I | Missense Mutation (SNP) | VAF 39/499 reads (8%) | SIFT tolerated (0.14); PolyPhen benign (0.062); called by muse, mutect2
- FAT2 | c.1943A>T p.Y648F | Missense Mutation (SNP) | VAF 22/468 reads (5%) | SIFT tolerated (0.8); PolyPhen benign (0.031); called by muse, mutect2
- FAT4 | c.14938G>A p.E4980K | Missense Mutation (SNP) | VAF 17/315 reads (5%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.969); called by muse, mutect2
- FBLN2 | c.1631C>T p.P544L | Missense Mutation (SNP) | VAF 33/516 reads (6%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.996); called by muse, mutect2
- FER1L6 | c.5188C>T p.L1730F | Missense Mutation (SNP) | VAF 21/505 reads (4%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.575); called by muse, mutect2
- FKRP | c.349C>T p.P117S | Missense Mutation (SNP) | VAF 40/740 reads (5%) | SIFT deleterious (0.02); PolyPhen benign (0.009); called by muse, mutect2
- FLG | c.2698G>A p.E900K | Missense Mutation (SNP) | VAF 38/618 reads (6%) | SIFT deleterious (0.04); PolyPhen benign (0); called by muse, mutect2
- FOXI3 | c.1090G>A p.D364N | Missense Mutation (SNP) | VAF 41/679 reads (6%) | SIFT tolerated (0.31); PolyPhen benign (0.346); called by muse, mutect2
- FOXN1 | c.76G>A p.D26N | Missense Mutation (SNP) | VAF 36/537 reads (7%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0.398); called by muse, mutect2
- FOXO3B | c.197C>T p.P66L | Missense Mutation (SNP) | VAF 22/506 reads (4%) | called by muse, mutect2
- FRMPD3 | c.1418G>A p.W473* | Nonsense Mutation (SNP) | VAF 37/206 reads (18%) | called by muse, mutect2, varscan2
- FRMPD4 | c.3G>A p.M1? | Translation Start Site (SNP) | VAF 23/309 reads (7%) | SIFT tolerated, low confidence (0.15); PolyPhen benign (0.003); called by muse, mutect2
- FSIP1 | c.508G>A p.E170K | Missense Mutation (SNP) | VAF 18/272 reads (7%) | SIFT deleterious (0.01); PolyPhen benign (0.403); called by muse, mutect2
- FSIP2 | c.11423G>A p.G3808E | Missense Mutation (SNP) | VAF 18/362 reads (5%) | SIFT tolerated (0.23); PolyPhen benign (0.015); called by muse, mutect2
- FSTL5 | c.1411G>A p.E471K | Missense Mutation (SNP) | VAF 18/339 reads (5%) | SIFT deleterious (0.01); PolyPhen benign (0.003); called by muse, mutect2
- GAB3 | c.853C>T p.Q285* | Nonsense Mutation (SNP) | VAF 28/273 reads (10%) | called by muse, mutect2
- GABRA3 | c.488A>C p.N163T | Missense Mutation (SNP) | VAF 35/288 reads (12%) | SIFT tolerated (0.24); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- GABRG2 | c.523G>A p.D175N | Missense Mutation (SNP) | VAF 19/380 reads (5%) | SIFT tolerated (0.52); PolyPhen probably damaging (0.997); called by muse, mutect2
- GCDH | c.1150C>T p.Q384* | Nonsense Mutation (SNP) | VAF 26/596 reads (4%) | called by muse, mutect2
- GDA | c.44G>A p.G15E | Missense Mutation (SNP) | VAF 23/479 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- GIMAP8 | c.478G>A p.D160N | Missense Mutation (SNP) | VAF 43/439 reads (10%) | SIFT tolerated (1); PolyPhen benign (0.003); called by muse, mutect2
- GLRA2 | c.269T>C p.M90T | Missense Mutation (SNP) | VAF 12/150 reads (8%) | SIFT deleterious (0); PolyPhen benign (0.12); called by muse, mutect2
- GPR139 | c.949C>T p.H317Y | Missense Mutation (SNP) | VAF 31/470 reads (7%) | SIFT deleterious (0.01); PolyPhen benign (0); called by muse, mutect2
- GPR179 | c.2023G>A p.D675N (on ENST00000621958; = p.D674N on NM_001004334.4) | Missense Mutation (SNP) | VAF 20/454 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); called by muse, mutect2
- GRID2 | c.787G>A p.E263K | Missense Mutation (SNP) | VAF 18/283 reads (6%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.973); called by muse, mutect2
- GRIK2 | c.2422G>A p.E808K | Missense Mutation (SNP) | VAF 26/506 reads (5%) | SIFT tolerated (0.62); PolyPhen benign (0.038); called by muse, mutect2
- GSTA5 | c.352G>A p.D118N | Missense Mutation (SNP) | VAF 41/386 reads (11%) | SIFT tolerated (0.06); PolyPhen benign (0.02); called by muse, mutect2, varscan2
- GUCY2F | c.1182G>A p.M394I | Missense Mutation (SNP) | VAF 17/211 reads (8%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2
- H1-7 | c.667G>A p.E223K | Missense Mutation (SNP) | VAF 21/600 reads (4%) | SIFT deleterious (0.01); PolyPhen benign (0.174); called by muse, mutect2
- HDGFL1 | c.311G>A p.G104E | Missense Mutation (SNP) | VAF 29/729 reads (4%) | SIFT tolerated (1); PolyPhen benign (0.026); called by muse, mutect2
- HECW2 | c.2305G>A p.G769R | Missense Mutation (SNP) | VAF 29/564 reads (5%) | SIFT tolerated, low confidence (0.18); PolyPhen possibly damaging (0.708); called by muse, mutect2
- HEPH | c.2624C>T p.S875F (on ENST00000343002; = p.S608F on NM_014799.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 23/218 reads (11%) | SIFT tolerated (0.39); PolyPhen probably damaging (0.947); called by muse, mutect2, varscan2
- HERC1 | c.428T>A p.V143D | Missense Mutation (SNP) | VAF 22/443 reads (5%) | SIFT tolerated (0.64); PolyPhen benign (0.043); called by muse, mutect2
- HLCS | c.385C>T p.P129S | Missense Mutation (SNP) | VAF 36/492 reads (7%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.988); called by muse, mutect2
- HTT | c.1573G>A p.D525N | Missense Mutation (SNP) | VAF 26/472 reads (6%) | SIFT tolerated (0.38); PolyPhen benign (0.011); called by muse, mutect2
- HTT | c.6769C>T p.L2257F | Missense Mutation (SNP) | VAF 15/270 reads (6%) | SIFT deleterious (0.01); PolyPhen benign (0.157); called by muse, mutect2
- IFNLR1 | c.313C>T p.P105S | Missense Mutation (SNP) | VAF 22/442 reads (5%) | SIFT tolerated (0.15); PolyPhen benign (0.001); called by muse, mutect2
- IGSF9B | c.448G>A p.E150K | Missense Mutation (SNP) | VAF 19/415 reads (5%) | SIFT deleterious (0.01); PolyPhen benign (0.23); called by muse, mutect2
- IL12B | c.72G>A p.W24* | Nonsense Mutation (SNP) | VAF 29/424 reads (7%) | called by muse, mutect2
- IL1RL1 | c.719G>A p.G240E | Missense Mutation (SNP) | VAF 19/384 reads (5%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); called by muse, mutect2
- ILDR1 | c.962G>A p.G321D (on ENST00000344209 / NM_001199799.2; = p.G277D on NM_175924.4) | Missense Mutation (SNP) | VAF 24/555 reads (4%) | SIFT tolerated (0.22); PolyPhen benign (0.011); called by muse, mutect2
- INF2 | c.3175C>T p.P1059S | Missense Mutation (SNP) | VAF 24/595 reads (4%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.014); called by muse, mutect2
- INHBA | c.566G>A p.G189E | Missense Mutation (SNP) | VAF 50/556 reads (9%) | SIFT tolerated (0.58); PolyPhen benign (0.003); called by muse, mutect2
- IPO9 | c.2336G>A p.G779E | Missense Mutation (SNP) | VAF 24/450 reads (5%) | SIFT deleterious (0); PolyPhen possibly damaging (0.874); called by muse, mutect2
- IQCA1 | c.2456G>A p.G819E | Missense Mutation (SNP) | VAF 20/297 reads (7%) | SIFT deleterious (0.03); PolyPhen benign (0.348); called by muse, mutect2
- IYD | c.466G>A p.E156K | Missense Mutation (SNP) | VAF 36/484 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- JAG1 | c.680C>T p.P227L | Missense Mutation (SNP) | VAF 25/370 reads (7%) | SIFT tolerated (0.15); PolyPhen benign (0.408); called by muse, mutect2
- JAKMIP2 | c.1480C>T p.L494F | Missense Mutation (SNP) | VAF 28/368 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); called by muse, mutect2
- JARID2 | c.3148C>T p.R1050C | Missense Mutation (SNP) | VAF 24/222 reads (11%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.877); called by muse, mutect2
- KAAG1 | c.116C>T p.P39L | Missense Mutation (SNP) | VAF 40/669 reads (6%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.146); called by muse, mutect2
- KCTD3 | c.541C>T p.P181S | Missense Mutation (SNP) | VAF 16/376 reads (4%) | SIFT tolerated (0.17); PolyPhen benign (0.015); called by muse, mutect2
- KIAA0232 | c.1561C>T p.P521S | Missense Mutation (SNP) | VAF 14/268 reads (5%) | SIFT tolerated (0.12); PolyPhen benign (0.096); called by muse, mutect2
- KIAA0319 | c.265G>A p.E89K | Missense Mutation (SNP) | VAF 57/525 reads (11%) | SIFT tolerated (0.09); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- KIAA1210 | c.1960G>A p.E654K | Missense Mutation (SNP) | VAF 30/222 reads (14%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.61); called by muse, mutect2, varscan2
- KIAA1217 | c.916C>T p.P306S | Missense Mutation (SNP) | VAF 28/663 reads (4%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.558); called by muse, mutect2
- KIAA1614 | c.2864C>T p.S955L | Missense Mutation (SNP) | VAF 25/466 reads (5%) | SIFT tolerated (0.37); PolyPhen benign (0); called by muse, mutect2
- KIF26A | c.4415C>T p.P1472L | Missense Mutation (SNP) | VAF 56/776 reads (7%) | SIFT deleterious (0); PolyPhen benign (0.003); called by muse, mutect2
- KIF26B | c.2837C>T p.P946L | Missense Mutation (SNP) | VAF 31/640 reads (5%) | SIFT tolerated (0.13); PolyPhen benign (0.135); called by muse, mutect2
- KIFC2 | c.2465C>T p.S822L | Missense Mutation (SNP) | VAF 38/657 reads (6%) | SIFT tolerated, low confidence (0.3); PolyPhen benign (0); called by muse, mutect2
- KLHDC7B | c.904G>A p.G302S (on ENST00000395676; = p.G943S on NM_138433.5) | Missense Mutation (SNP) | VAF 40/614 reads (7%) | SIFT tolerated (0.46); PolyPhen benign (0.02); called by muse, mutect2
- KLHL6 | c.817G>A p.E273K | Missense Mutation (SNP) | VAF 22/412 reads (5%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.515); called by muse, mutect2
- KRT1 | c.131G>A p.G44E | Missense Mutation (SNP) | VAF 37/618 reads (6%) | SIFT deleterious (0.02); PolyPhen benign (0.159); called by muse, mutect2
- KRTAP1-4 | c.260G>T p.C87F | Missense Mutation (SNP) | VAF 56/632 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2
- KRTAP3-1 | c.23C>T p.S8F | Missense Mutation (SNP) | VAF 24/432 reads (6%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.04); called by muse, mutect2
- KRTAP5-11 | c.446C>T p.P149L | Missense Mutation (SNP) | VAF 31/587 reads (5%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.993); called by muse, mutect2
- KXD1 | c.252C>T p.I84= | Splice Region (SNP) | VAF 16/294 reads (5%) | called by muse, mutect2
- LACTB2 | c.104T>C p.L35P | Missense Mutation (SNP) | VAF 28/369 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- LANCL2 | c.656T>C p.V219A | Missense Mutation (SNP) | VAF 45/298 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.81); called by muse, mutect2, varscan2
- LOXHD1 | c.1984G>A p.D662N | Missense Mutation (SNP) | VAF 23/356 reads (6%) | SIFT tolerated (1); PolyPhen benign (0.022); called by muse, mutect2
- LPAR1 | c.53C>T p.A18V | Missense Mutation (SNP) | VAF 15/242 reads (6%) | SIFT tolerated (0.36); PolyPhen benign (0.045); called by muse, mutect2
- LRIG1 | c.936G>A p.L312= | Splice Region (SNP) | VAF 20/262 reads (8%) | called by muse, mutect2
- LRIT2 | c.583G>A p.V195M | Missense Mutation (SNP) | VAF 25/492 reads (5%) | SIFT deleterious (0.03); PolyPhen benign (0.001); called by muse, mutect2
- LRRC55 | c.47C>T p.P16L | Missense Mutation (SNP) | VAF 33/620 reads (5%) | SIFT deleterious (0.04); PolyPhen benign (0.023); called by muse, mutect2
- LY9 | c.749G>A p.G250E | Missense Mutation (SNP) | VAF 24/378 reads (6%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.857); called by muse, mutect2
- MAB21L3 | c.98A>C p.K33T | Missense Mutation (SNP) | VAF 34/528 reads (6%) | SIFT tolerated (0.06); PolyPhen benign (0.36); called by muse, mutect2
- MADD | c.2338C>T p.P780S | Missense Mutation (SNP) | VAF 27/518 reads (5%) | SIFT deleterious, low confidence (0.03); PolyPhen probably damaging (0.998); called by muse, mutect2
- MAP3K4 | c.1106C>T p.P369L | Missense Mutation (SNP) | VAF 22/428 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- MAP6 | c.250G>A p.G84R | Missense Mutation (SNP) | VAF 23/269 reads (9%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.99); called by muse, mutect2
- MASP1 | c.16C>T p.L6F | Missense Mutation (SNP) | VAF 18/344 reads (5%) | SIFT tolerated (0.08); PolyPhen benign (0.041); called by muse, mutect2
- MAST1 | c.2614G>A p.D872N | Missense Mutation (SNP) | VAF 30/494 reads (6%) | SIFT tolerated, low confidence (0.31); PolyPhen benign (0.4); called by muse, mutect2
- MCM2 | c.11C>T p.S4L | Missense Mutation (SNP) | VAF 14/321 reads (4%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.081); called by muse, mutect2
- MCM9 | c.2851C>T p.H951Y | Missense Mutation (SNP) | VAF 32/346 reads (9%) | SIFT tolerated, low confidence (0.97); PolyPhen benign (0.007); called by muse, mutect2
- METTL22 | c.262C>T p.P88S | Missense Mutation (SNP) | VAF 31/523 reads (6%) | SIFT tolerated (0.3); PolyPhen benign (0.007); called by muse, mutect2
- MIA2 | c.266G>A p.G89E | Missense Mutation (SNP) | VAF 14/286 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- MLXIPL | c.2002G>A p.G668R | Missense Mutation (SNP) | VAF 46/298 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- MMP28 | c.563G>A p.G188E | Missense Mutation (SNP) | VAF 28/658 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- MN1 | c.58G>A p.E20K | Missense Mutation (SNP) | VAF 20/436 reads (5%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.458); called by muse, mutect2
- MROH9 | c.1784C>T p.S595F | Missense Mutation (SNP) | VAF 22/346 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- MSGN1 | c.101G>A p.G34E | Missense Mutation (SNP) | VAF 41/518 reads (8%) | SIFT tolerated (0.25); PolyPhen benign (0.055); called by muse, mutect2
- MTOR | c.947T>C p.F316S | Missense Mutation (SNP) | VAF 35/613 reads (6%) | SIFT tolerated (0.3); PolyPhen probably damaging (0.91); called by muse, mutect2
- MTUS1 | c.859A>T p.K287* | Nonsense Mutation (SNP) | VAF 30/516 reads (6%) | called by muse, mutect2
- MUC16 | c.29470C>T p.H9824Y | Missense Mutation (SNP) | VAF 22/394 reads (6%) | SIFT tolerated, low confidence (0.21); PolyPhen benign (0.009); called by muse, mutect2
- MUC16 | c.6158G>A p.W2053* | Nonsense Mutation (SNP) | VAF 26/490 reads (5%) | called by muse, mutect2
- MUC22 | c.1810G>A p.E604K | Missense Mutation (SNP) | VAF 83/432 reads (19%) | SIFT tolerated (0.26); called by muse, mutect2, varscan2
- MXRA5 | c.1351G>A p.V451M | Missense Mutation (SNP) | VAF 24/206 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.945); called by muse, mutect2, varscan2
- MYH2 | c.3436T>A p.S1146T | Missense Mutation (SNP) | VAF 28/615 reads (5%) | SIFT tolerated (0.18); PolyPhen benign (0.03); called by muse, mutect2
- MYO18B | c.1664C>T p.T555I | Missense Mutation (SNP) | VAF 19/374 reads (5%) | SIFT tolerated (0.37); PolyPhen benign (0.039); called by muse, mutect2
- NAV3 | c.6158T>A p.I2053K (on ENST00000397909 / NM_001024383.2; = p.I2031K on NM_014903.6) | Missense Mutation (SNP) | VAF 24/426 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- NDRG1 | c.887C>T p.S296F | Missense Mutation (SNP) | VAF 24/532 reads (5%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.717); called by muse, mutect2
- NEFL | c.1217G>A p.G406E | Missense Mutation (SNP) | VAF 29/411 reads (7%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.889); called by muse, mutect2
- NEFM | c.1886C>T p.P629L | Missense Mutation (SNP) | VAF 39/692 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.908); called by muse, mutect2
- NEGR1 | c.596G>A p.G199E | Missense Mutation (SNP) | VAF 32/360 reads (9%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.986); called by muse, mutect2
- NEURL1B | c.371C>T p.T124M | Missense Mutation (SNP) | VAF 26/668 reads (4%) | SIFT deleterious (0); PolyPhen possibly damaging (0.832); called by muse, mutect2
- NEXMIF | c.1561G>A p.D521N | Missense Mutation (SNP) | VAF 39/272 reads (14%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.961); called by muse, mutect2, varscan2
- NEXMIF | c.823C>T p.L275F | Missense Mutation (SNP) | VAF 20/240 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.799); called by muse, mutect2
- NFAT5 | c.4048C>T p.P1350S | Missense Mutation (SNP) | VAF 24/349 reads (7%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2
- NFKBIA | c.757C>T p.P253S | Missense Mutation (SNP) | VAF 28/546 reads (5%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.998); called by muse, mutect2
- NID1 | c.2386G>A p.D796N | Missense Mutation (SNP) | VAF 28/392 reads (7%) | SIFT tolerated (0.08); PolyPhen benign (0.013); called by muse, mutect2
- NIPSNAP1 | c.715G>A p.D239N | Missense Mutation (SNP) | VAF 22/412 reads (5%) | SIFT tolerated (0.09); PolyPhen benign (0.394); called by muse, mutect2
- NLGN1 | c.1213G>A p.G405S | Missense Mutation (SNP) | VAF 16/356 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); called by muse, mutect2
- NLRC3 | c.235G>A p.E79K | Missense Mutation (SNP) | VAF 36/590 reads (6%) | SIFT deleterious (0.04); PolyPhen benign (0.214); called by muse, mutect2
- NMS | c.401T>A p.F134Y | Missense Mutation (SNP) | VAF 18/388 reads (5%) | SIFT tolerated (0.38); PolyPhen probably damaging (0.999); called by muse, mutect2
- NOB1 | c.1202C>T p.P401L | Missense Mutation (SNP) | VAF 22/378 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.948); called by muse, mutect2
- NOC2L | c.997C>T p.L333F | Missense Mutation (SNP) | VAF 20/346 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); called by muse, mutect2
- NOS2 | c.1636G>A p.E546K | Missense Mutation (SNP) | VAF 28/528 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- NSUN3 | c.896C>T p.S299F | Missense Mutation (SNP) | VAF 32/480 reads (7%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.927); called by muse, mutect2
- NSUN5 | c.1151C>T p.A384V | Missense Mutation (SNP) | VAF 18/336 reads (5%) | SIFT tolerated (0.72); PolyPhen benign (0.006); called by muse, mutect2
- NT5DC4 | c.203G>A p.R68K | Missense Mutation (SNP) | VAF 22/510 reads (4%) | SIFT deleterious (0); PolyPhen possibly damaging (0.503); called by muse, mutect2
- NWD1 | c.2072A>G p.Q691R | Missense Mutation (SNP) | VAF 22/496 reads (4%) | SIFT tolerated (0.15); PolyPhen benign (0.139); called by muse, mutect2
- NXPE2 | c.1562T>C p.L521P | Missense Mutation (SNP) | VAF 34/482 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); called by muse, mutect2
- OLIG3 | c.238G>A p.D80N | Missense Mutation (SNP) | VAF 20/510 reads (4%) | SIFT deleterious (0.04); PolyPhen benign (0.366); called by muse, mutect2
- OOSP4A | c.89C>T p.S30F | Missense Mutation (SNP) | VAF 20/299 reads (7%) | SIFT tolerated (0.7); PolyPhen benign (0.028); called by muse, mutect2
- OPLAH | c.1709C>T p.S570F | Missense Mutation (SNP) | VAF 20/277 reads (7%) | SIFT tolerated (0.09); PolyPhen benign (0.117); called by muse, mutect2
- OR13C2 | c.548C>T p.A183V | Missense Mutation (SNP) | VAF 15/316 reads (5%) | SIFT deleterious (0.02); PolyPhen benign (0.314); called by muse, mutect2
- OR1J1 | c.465T>G p.C155W | Missense Mutation (SNP) | VAF 52/521 reads (10%) | SIFT tolerated, low confidence (0.12); PolyPhen possibly damaging (0.796); called by muse, mutect2
- OR1R1P | c.679C>T p.R227W | Missense Mutation (SNP) | VAF 30/443 reads (7%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.837); called by muse, mutect2
- OR2F2 | c.742G>A p.V248I | Missense Mutation (SNP) | VAF 43/362 reads (12%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- OR4C13 | c.215C>T p.S72F | Missense Mutation (SNP) | VAF 30/406 reads (7%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.954); called by muse, mutect2
- OR52W1 | c.643G>A p.D215N | Missense Mutation (SNP) | VAF 20/442 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.966); called by muse, mutect2
- OR5AK2 | c.121G>A p.G41S | Missense Mutation (SNP) | VAF 21/432 reads (5%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.45); called by muse, mutect2
- OSBP2 | c.1405G>A p.A469T | Missense Mutation (SNP) | VAF 20/290 reads (7%) | SIFT tolerated (0.23); PolyPhen benign (0.003); called by muse, mutect2
- OTOG | c.3230G>A p.G1077E | Missense Mutation (SNP) | VAF 33/476 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- OTULINL | c.439C>T p.Q147* | Nonsense Mutation (SNP) | VAF 24/446 reads (5%) | called by muse, mutect2
- OVOL2 | c.709C>T p.H237Y | Missense Mutation (SNP) | VAF 23/455 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- PABPC4L | c.284C>T p.S95F | Missense Mutation (SNP) | VAF 29/341 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2
- PADI6 | c.1240G>A p.D414N | Missense Mutation (SNP) | VAF 23/383 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- PAPPA2 | c.358G>A p.G120S | Missense Mutation (SNP) | VAF 20/480 reads (4%) | SIFT tolerated, low confidence (0.57); PolyPhen benign (0); called by muse, mutect2
- PCDHA2 | c.1181C>T p.P394L | Missense Mutation (SNP) | VAF 18/496 reads (4%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.793); called by muse, mutect2
- PCDHB11 | c.1616C>T p.P539L | Missense Mutation (SNP) | VAF 54/1235 reads (4%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (1); called by muse, mutect2
- PCDHB8 | c.842C>T p.S281L | Missense Mutation (SNP) | VAF 23/363 reads (6%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.291); called by muse, mutect2
- PCLO | c.4313C>T p.P1438L | Missense Mutation (SNP) | VAF 35/493 reads (7%) | SIFT tolerated (0.35); PolyPhen benign (0.001); called by muse, mutect2
- PDE1C | c.343G>A p.G115R | Missense Mutation (SNP) | VAF 61/483 reads (13%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.688); called by muse, mutect2, varscan2
- PEF1 | c.290C>T p.S97F | Missense Mutation (SNP) | VAF 24/406 reads (6%) | SIFT tolerated (0.1); PolyPhen benign (0.123); called by muse, mutect2
- PEG3 | c.2734G>A p.G912R | Missense Mutation (SNP) | VAF 24/450 reads (5%) | SIFT tolerated (0.23); PolyPhen possibly damaging (0.903); called by muse, mutect2
- PEX14 | c.178G>A p.D60N | Missense Mutation (SNP) | VAF 14/285 reads (5%) | SIFT tolerated (0.07); PolyPhen benign (0.103); called by muse, mutect2
- PGK2 | c.161G>A p.G54E | Missense Mutation (SNP) | VAF 54/469 reads (12%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.94); called by muse, mutect2, varscan2
- PGR | c.1597G>A p.G533S | Missense Mutation (SNP) | VAF 16/416 reads (4%) | SIFT tolerated (0.39); PolyPhen benign (0.012); called by muse, mutect2
- PHKA2 | c.2245C>T p.Q749* | Nonsense Mutation (SNP) | VAF 18/153 reads (12%) | called by muse, mutect2, varscan2
- PHLDB2 | c.1624G>A p.E542K | Missense Mutation (SNP) | VAF 22/513 reads (4%) | SIFT tolerated (0.14); PolyPhen benign (0); called by muse, mutect2
- PIK3C2A | c.505C>T p.Q169* | Nonsense Mutation (SNP) | VAF 31/461 reads (7%) | called by muse, mutect2
- PIPOX | c.248G>A p.G83E | Missense Mutation (SNP) | VAF 15/313 reads (5%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.593); called by muse, mutect2
- PIPOX | c.691G>A p.E231K | Missense Mutation (SNP) | VAF 24/436 reads (6%) | SIFT deleterious (0.02); PolyPhen benign (0.159); called by muse, mutect2
- PITRM1 | c.2342C>T p.S781L | Missense Mutation (SNP) | VAF 16/298 reads (5%) | SIFT deleterious (0); PolyPhen possibly damaging (0.691); called by muse, mutect2
- PKD1 | c.9329C>T p.P3110L | Missense Mutation (SNP) | VAF 27/699 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.97); called by muse, mutect2
- PKHD1L1 | c.5257G>A p.G1753R | Missense Mutation (SNP) | VAF 31/450 reads (7%) | SIFT tolerated (0.71); PolyPhen benign (0.005); called by muse, mutect2
- PLCB1 | c.2774A>T p.K925I | Missense Mutation (SNP) | VAF 20/392 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.965); called by muse, mutect2
- PLCB4 | c.1466C>T p.P489L | Missense Mutation (SNP) | VAF 20/366 reads (5%) | SIFT tolerated (0.05); PolyPhen benign (0.244); called by muse, mutect2
- PLEKHA7 | c.1108G>A p.E370K | Missense Mutation (SNP) | VAF 22/430 reads (5%) | SIFT tolerated (0.82); PolyPhen benign (0.001); called by muse, mutect2
- PORCN | c.1015C>T p.L339F (on ENST00000326194 / NM_203475.3; = p.L328F on NM_022825.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 15/221 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- POU3F4 | c.1012C>T p.P338S | Missense Mutation (SNP) | VAF 22/201 reads (11%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.771); called by muse, mutect2, varscan2
- POU6F2 | c.931G>A p.A311T | Missense Mutation (SNP) | VAF 23/368 reads (6%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.003); called by muse, mutect2
- PPARGC1A | c.1796C>T p.S599F | Missense Mutation (SNP) | VAF 24/338 reads (7%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.962); called by muse, mutect2
- PPFIA4 | c.2995C>T p.Q999* (on ENST00000447715; = p.Q1000* on NM_001304331.2 and 1 other RefSeq transcript) | Nonsense Mutation (SNP) | VAF 15/254 reads (6%) | called by muse, mutect2
- PPP1R16B | c.16G>A p.D6N | Missense Mutation (SNP) | VAF 32/528 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.652); called by muse, mutect2
- PRAG1 | c.3587C>T p.A1196V | Missense Mutation (SNP) | VAF 26/450 reads (6%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.234); called by muse, mutect2
- PRAMEF19 | c.469G>A p.E157K | Missense Mutation (SNP) | VAF 29/501 reads (6%) | SIFT tolerated (0.32); PolyPhen benign (0.007); called by muse, mutect2
- PRDM13 | c.89C>T p.T30I | Missense Mutation (SNP) | VAF 33/618 reads (5%) | SIFT tolerated (0.49); PolyPhen benign (0.001); called by muse, mutect2
- PRG3 | c.121G>A p.D41N | Missense Mutation (SNP) | VAF 32/470 reads (7%) | SIFT deleterious (0.01); PolyPhen benign (0.107); called by muse, mutect2
- PRLR | c.1493A>T p.K498I | Missense Mutation (SNP) | VAF 20/430 reads (5%) | SIFT deleterious (0); PolyPhen possibly damaging (0.836); called by muse, mutect2
- PRPF4B | c.1069C>T p.P357S | Missense Mutation (SNP) | VAF 26/406 reads (6%) | SIFT tolerated, low confidence (0.08); PolyPhen probably damaging (0.994); called by muse, mutect2
- PRR5 | c.295C>T p.L99F (on ENST00000336985 / NM_181333.4; = p.L90F on NM_015366.4) | Missense Mutation (SNP) | VAF 34/436 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
661 further variants in this file (131 protein-altering or splice-affecting, 473 silent, 57 other) are not listed here.
